Somatic mutation profile of tumor specimen TCGA-B5-A11N-01A (aliquot TCGA-B5-A11N-01A-11D-A122-09) from TCGA case TCGA-B5-A11N, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G1; Age at diagnosis: 69.7 years (25,442 days).
Specimen TCGA-B5-A11N-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fd78fcd1-c39b-45e5-959e-7527fa636346.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B5-A11N-10A (Blood Derived Normal), aliquot TCGA-B5-A11N-10A-01D-A122-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8ac99de1-18b8-4f7d-96df-171cbd093eaa

The open-access MAF lists 2,108 somatic variants for this specimen: 1,696 protein-altering or splice-affecting, 375 silent, 37 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,400, Silent 375, Nonsense Mutation 248, Splice Site 21, Intron 21, Splice Region 14, RNA 7, Frame Shift Ins 6, 5'UTR 3, 3'UTR 3, 3'Flank 2, Translation Start Site 2.

Variants (750 of 2,108; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASPM | c.9454C>T p.R3152* | Nonsense Mutation (SNP) | VAF 58/192 reads (30%) | catalogued as rs587783292, CM142031, COSV54124029; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FBXL4 | c.1411G>A p.A471T | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs1227524799, COSV57744762; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- FBXW7 | c.1394G>A p.R465H (on ENST00000281708 / NM_001349798.2; = p.R385H on NM_018315.5) | Missense Mutation (SNP) | VAF 85/351 reads (24%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519895, COSV55891746, COSV55897262, COSV55941157; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- GAN | c.601C>T p.R201* | Nonsense Mutation (SNP) | VAF 37/134 reads (28%) | catalogued as rs119485090, CM020938, COSV101633963; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.182A>T p.Q61L | Missense Mutation (SNP) | VAF 82/310 reads (26%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.631); catalogued as rs121913240, COSV55498739, COSV55504296, COSV55508574; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- MECP2 | c.253C>T p.R85C | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); catalogued as rs1064797047, COSV57651600; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- MGA | c.3724C>T p.R1242* | Nonsense Mutation (SNP) | VAF 97/388 reads (25%) | hotspot (GDC flag); catalogued as COSV54948051; called by muse, mutect2, varscan2
- MTM1 | c.1490C>A p.S497Y | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs587783800, COSV60333561; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- NDUFB11 | c.361G>A p.E121K (on ENST00000377811 / NM_001135998.3; = p.E131K on NM_019056.6) | Missense Mutation (SNP) | VAF 52/235 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519073, CM161306, COSV52101747; ClinVar: pathogenic; called by muse, mutect2
- NGLY1 | c.1624C>T p.R542* | Nonsense Mutation (SNP) | VAF 58/197 reads (29%) | catalogued as rs528583612, CM146810, COSV54983506; ClinVar: pathogenic; called by muse, mutect2, varscan2
- POLE | c.857C>G p.P286R | Missense Mutation (SNP) | VAF 62/207 reads (30%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519943, COSV57673247, COSV57678855; ClinVar: uncertain significance / likely pathogenic / drug response; called by muse, mutect2, varscan2
- PTEN | c.19G>T p.E7* | Nonsense Mutation (SNP) | VAF 81/385 reads (21%) | catalogued as rs1554890335, COSV64288471, COSV64291810; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.517C>T p.R173C | Missense Mutation (SNP) | VAF 93/379 reads (25%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as rs121913293, CM074467, COSV64288569, COSV64310838; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- SLC26A4 | c.269C>T p.S90L | Missense Mutation (SNP) | VAF 77/266 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs370588279, CM030956, COSV55914262; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- XPO1 | c.1711G>A p.E571K | Missense Mutation (SNP) | VAF 64/205 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057520009, COSV68944533, COSV68945324; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- A2ML1 | c.3116C>T p.A1039V | Missense Mutation (SNP) | VAF 45/186 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs769398333, COSV55285108; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AADACL3 | c.796G>A p.V266I | Missense Mutation (SNP) | VAF 44/269 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.02); catalogued as COSV60198006; called by muse, mutect2, varscan2
- ABCA10 | c.4300G>A p.D1434N | Missense Mutation (SNP) | VAF 124/345 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0.134); catalogued as COSV52217810; called by muse, mutect2, varscan2
- ABCA12 | c.6100A>C p.N2034H (on ENST00000272895 / NM_173076.3; = p.N1716H on NM_015657.3) | Missense Mutation (SNP) | VAF 106/429 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV55948348; called by muse, mutect2, varscan2
- ABCA12 | c.4544G>A p.R1515Q (on ENST00000272895 / NM_173076.3; = p.R1197Q on NM_015657.3) | Missense Mutation (SNP) | VAF 91/337 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as rs774279263, CM1311790, COSV55948366; called by muse, mutect2, varscan2
- ABCA12 | c.1699G>T p.E567* (on ENST00000272895 / NM_173076.3; = p.E249* on NM_015657.3) | Nonsense Mutation (SNP) | VAF 106/452 reads (23%) | catalogued as COSV55948386, COSV99792722; called by muse, mutect2, varscan2
- ABCA13 | c.13344G>T p.K4448N | Missense Mutation (SNP) | VAF 89/329 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.355); catalogued as COSV68942924; called by muse, mutect2, varscan2
- ABCA4 | c.3883G>T p.E1295* | Nonsense Mutation (SNP) | VAF 4/38 reads (11%) | catalogued as COSV64679321; called by muse, mutect2
- ABCB1 | c.836A>C p.K279T | Missense Mutation (SNP) | VAF 80/545 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.159); catalogued as COSV55944562; called by muse, mutect2, varscan2
- ABCB6 | c.856T>G p.Y286D | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.898); catalogued as COSV54692534; called by muse, mutect2, varscan2
- ABCC9 | c.64A>C p.N22H | Missense Mutation (SNP) | VAF 127/454 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53961868; called by muse, mutect2, varscan2
- ABHD14A-ACY1 | c.491T>G p.F164C | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT deleterious, low confidence (0); catalogued as COSV56472633, COSV99865558; called by muse, mutect2
- ABR | c.459C>A p.F153L (on ENST00000302538 / NM_021962.5; = p.F116L on NM_001092.5) | Missense Mutation (SNP) | VAF 89/222 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); catalogued as COSV52141061; called by muse, mutect2, varscan2
- ABRAXAS2 | c.623C>T p.A208V | Missense Mutation (SNP) | VAF 346/792 reads (44%) | SIFT tolerated (0.16); PolyPhen benign (0.006); catalogued as rs762495232, COSV100045096; called by muse, mutect2
- ACAD11 | c.706C>T p.R236* | Nonsense Mutation (SNP) | VAF 10/200 reads (5%) | catalogued as rs1256200245, COSV99392559; called by muse, mutect2
- ACAD9 | c.112G>A p.A38T | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as COSV58306386; called by muse, mutect2, varscan2
- ACE2 | c.78G>T p.K26N | Missense Mutation (SNP) | VAF 78/301 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.013); catalogued as COSV53023464; called by muse, mutect2, varscan2
- ACMSD | c.37G>T p.E13* | Nonsense Mutation (SNP) | VAF 84/376 reads (22%) | catalogued as COSV51605373; called by muse, mutect2, varscan2
- ACRBP | c.868C>T p.R290* | Nonsense Mutation (SNP) | VAF 8/178 reads (4%) | catalogued as COSV57523840, COSV57524678; called by muse, mutect2
- ACSL1 | c.1990T>G p.S664A | Missense Mutation (SNP) | VAF 35/134 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.076); catalogued as COSV55660419; called by muse, mutect2, varscan2
- ACSL4 | c.316A>C p.N106H (on ENST00000340800 / NM_022977.2; = p.N65H on NM_004458.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 130/409 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.615); catalogued as COSV61613076; called by muse, mutect2, varscan2
- ACSM1 | c.398G>A p.R133Q | Missense Mutation (SNP) | VAF 60/197 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs769122330, COSV54632818; called by muse, mutect2, varscan2
- ACSM3 | c.1606G>T p.E536* | Nonsense Mutation (SNP) | VAF 94/385 reads (24%) | catalogued as COSV55499590; called by muse, mutect2, varscan2
- ACSS3 | c.1661G>A p.R554Q | Missense Mutation (SNP) | VAF 164/667 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs778280883, COSV54083909; called by muse, mutect2, varscan2
- ACTL6A | c.322A>G p.K108E | Missense Mutation (SNP) | VAF 20/384 reads (5%) | SIFT tolerated (0.49); PolyPhen benign (0.254); catalogued as COSV101199719; called by muse, mutect2
- ACTR5 | c.1015A>G p.M339V | Missense Mutation (SNP) | VAF 63/279 reads (23%) | SIFT tolerated (0.45); PolyPhen benign (0.009); catalogued as COSV54759714; called by muse, mutect2, varscan2
- ACTR8 | c.164C>T p.S55L | Missense Mutation (SNP) | VAF 77/392 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51634970; called by muse, mutect2, varscan2
- ACTRT3 | c.638A>C p.E213A | Missense Mutation (SNP) | VAF 100/391 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57753726; called by muse, mutect2, varscan2
- ADAD1 | c.1570G>T p.E524* | Nonsense Mutation (SNP) | VAF 59/245 reads (24%) | catalogued as COSV56641200; called by muse, mutect2, varscan2
- ADAM19 | c.619A>C p.N207H | Missense Mutation (SNP) | VAF 67/303 reads (22%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV57422315; called by muse, mutect2, varscan2
- ADAM7 | c.1393G>T p.D465Y | Missense Mutation (SNP) | VAF 42/164 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV51534609; called by muse, mutect2, varscan2
- ADAM9 | c.767G>A p.R256Q | Missense Mutation (SNP) | VAF 14/404 reads (3%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.506); catalogued as rs1344174952, COSV65946589; called by muse, mutect2
- ADAMTS10 | c.823T>G p.F275V | Missense Mutation (SNP) | VAF 60/211 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54351693; called by muse, mutect2, varscan2
- ADAMTS16 | c.2478G>T p.E826D | Missense Mutation (SNP) | VAF 36/92 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56976773, COSV56980243; called by muse, mutect2, varscan2
- ADAMTS18 | c.2081T>G p.F694C | Missense Mutation (SNP) | VAF 121/447 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs267604650, COSV51398325, COSV51398570; called by muse, mutect2, varscan2
- ADCY5 | c.2279G>A p.R760Q | Missense Mutation (SNP) | VAF 37/201 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.067); catalogued as rs766054571, COSV59193829; called by muse, mutect2, varscan2
- ADCY8 | c.3005A>G p.N1002S | Missense Mutation (SNP) | VAF 72/277 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.855); catalogued as COSV53895155; called by muse, mutect2, varscan2
- ADCY9 | c.1462G>A p.V488I | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.27); catalogued as COSV53571228; called by muse, mutect2, varscan2
- ADD2 | c.1799C>T p.S600F | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.635); catalogued as COSV52454333; called by muse, mutect2, varscan2
- ADGRB3 | c.1223C>T p.S408L | Missense Mutation (SNP) | VAF 86/306 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs766735540, COSV65381042; called by muse, mutect2, varscan2
- ADGRE1 | c.1327G>T p.E443* | Nonsense Mutation (SNP) | VAF 73/266 reads (27%) | catalogued as COSV51671532, COSV51672387; called by muse, mutect2, varscan2
- ADGRF5 | c.1650G>T p.K550N | Missense Mutation (SNP) | VAF 67/292 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.899); catalogued as rs147958492; called by muse, mutect2, varscan2
- ADGRG4 | c.7699G>A p.A2567T | Missense Mutation (SNP) | VAF 70/352 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.644); catalogued as COSV54948615; called by muse, mutect2, varscan2
- ADGRG4 | c.7887C>A p.F2629L | Missense Mutation (SNP) | VAF 17/427 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1334865153, COSV99794222; called by muse, mutect2
- ADGRG7 | c.1987A>C p.K663Q | Missense Mutation (SNP) | VAF 91/438 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV56293372; called by muse, mutect2, varscan2
- ADGRL2 | c.1054G>T p.E352* | Nonsense Mutation (SNP) | VAF 86/303 reads (28%) | catalogued as COSV54650261; called by muse, mutect2, varscan2
- ADGRV1 | c.6599C>A p.S2200Y | Missense Mutation (SNP) | VAF 70/308 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs771621314, COSV67977781; called by muse, mutect2, varscan2
- ADH1C | c.744G>T p.K248N | Missense Mutation (SNP) | VAF 214/777 reads (28%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as COSV72463375; called by muse, mutect2, varscan2
- ADH6 | c.154A>G p.K52E | Missense Mutation (SNP) | VAF 82/235 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV52954833; called by muse, mutect2, varscan2
- ADSS1 | c.588C>A p.F196L | Missense Mutation (SNP) | VAF 58/199 reads (29%) | SIFT tolerated (0.49); PolyPhen benign (0.143); catalogued as COSV58271886; called by muse, mutect2, varscan2
- AFF2 | c.2724G>T p.K908N | Missense Mutation (SNP) | VAF 11/197 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.31); catalogued as COSV99665842; called by muse, mutect2
- AFF2 | c.2906C>T p.S969L | Missense Mutation (SNP) | VAF 60/216 reads (28%) | SIFT tolerated (0.39); PolyPhen benign (0.137); catalogued as rs782779717, COSV53975111; called by muse, mutect2, varscan2
- AFF2 | c.3446C>T p.S1149L | Missense Mutation (SNP) | VAF 125/422 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); catalogued as rs1341384078, COSV53975147; called by muse, mutect2, varscan2
- AFF3 | c.2629C>T p.R877W | Missense Mutation (SNP) | VAF 123/462 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.139); catalogued as rs190577667, COSV57838935; called by muse, mutect2, varscan2
- AFM | c.435A>C p.E145D | Missense Mutation (SNP) | VAF 76/255 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.979); catalogued as COSV56918896; called by muse, mutect2, varscan2
- AFTPH | c.1939G>A p.A647T | Missense Mutation (SNP) | VAF 8/143 reads (6%) | SIFT tolerated (0.68); PolyPhen benign (0.009); catalogued as rs1351821239, COSV99481137; called by muse, mutect2
- AGGF1 | c.1681G>T p.E561* | Nonsense Mutation (SNP) | VAF 54/281 reads (19%) | catalogued as COSV57227576, COSV57228398; called by muse, mutect2, varscan2
- AGO3 | c.2065C>T p.R689* | Nonsense Mutation (SNP) | VAF 66/209 reads (32%) | catalogued as rs1244575080, COSV55790721, COSV55792811; called by muse, mutect2, varscan2
- AGPAT3 | c.1057C>T p.R353C | Missense Mutation (SNP) | VAF 39/161 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV52367458; called by muse, mutect2, varscan2
- AGXT | c.181A>G p.K61E | Missense Mutation (SNP) | VAF 14/120 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV56753048; called by muse, mutect2, varscan2
- AHCTF1 | c.6889C>T p.R2297C (on ENST00000366508; = p.R2271C on NM_015446.5) | Missense Mutation (SNP) | VAF 47/276 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs370639205, COSV58245489; called by muse, mutect2, varscan2
- AHNAK | c.682G>A p.A228T | Missense Mutation (SNP) | VAF 33/114 reads (29%) | SIFT tolerated (0.59); PolyPhen benign (0.165); catalogued as rs532677749, COSV57202704; called by muse, mutect2, varscan2
- AK9 | c.3519G>T p.K1173N | Missense Mutation (SNP) | VAF 190/708 reads (27%) | SIFT tolerated (0.47); PolyPhen benign (0.025); catalogued as COSV100393216, COSV58136679; called by muse, mutect2, varscan2
- AKIRIN2 | c.476G>A p.R159H | Missense Mutation (SNP) | VAF 131/581 reads (23%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.938); catalogued as COSV57635878; called by muse, mutect2, varscan2
- AKT3 | c.1192G>T p.E398* | Nonsense Mutation (SNP) | VAF 57/370 reads (15%) | catalogued as COSV55606314; called by muse, mutect2, varscan2
- ALCAM | c.1225A>G p.T409A | Missense Mutation (SNP) | VAF 11/111 reads (10%) | SIFT tolerated (0.62); PolyPhen benign (0.266); catalogued as COSV100065496; called by muse, mutect2
- ALDH7A1 | c.355G>A p.D119N | Missense Mutation (SNP) | VAF 47/252 reads (19%) | SIFT tolerated (0.33); PolyPhen benign (0.221); catalogued as rs1212969829, COSV68628555; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ALG13 | c.1780C>T p.R594* | Nonsense Mutation (SNP) | VAF 73/271 reads (27%) | catalogued as COSV52634896; called by muse, mutect2, varscan2
- ALPK3 | c.3154C>T p.R1052C | Missense Mutation (SNP) | VAF 4/7 reads (57%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs745957839, COSV51928873, COSV99362190; called by mutect2, varscan2
- ALPL | c.73G>T p.D25Y | Missense Mutation (SNP) | VAF 26/113 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV100876902, COSV66379384; called by muse, mutect2, varscan2
- AMER3 | c.481C>T p.R161W | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.071); catalogued as rs949105785, COSV58465006; called by muse, mutect2, varscan2
- AMHR2 | c.65G>A p.R22Q | Missense Mutation (SNP) | VAF 28/108 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs747962250, COSV57684860; called by muse, mutect2, varscan2
- AMOTL2 | c.1031G>A p.R344H | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.609); catalogued as rs369381825; called by muse, mutect2, varscan2
- ANAPC1 | c.4736C>A p.S1579Y | Missense Mutation (SNP) | VAF 74/679 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as COSV61974077; called by muse, mutect2, varscan2
- ANGPT1 | c.1375G>T p.G459* | Nonsense Mutation (SNP) | VAF 29/570 reads (5%) | catalogued as COSV99863861; called by muse, mutect2
- ANK3 | c.12687C>T p.S4229= (on ENST00000280772 / NM_001320874.2; = p.S853= on NM_001149.3) | Splice Region (SNP) | VAF 57/185 reads (31%) | catalogued as rs1356481812, COSV55042855; called by muse, mutect2, varscan2
- ANKMY1 | c.2259+1G>A p.X753_splice | Splice Site (SNP) | VAF 22/90 reads (24%) | catalogued as COSV56029733; called by muse, mutect2, varscan2
- ANKRD12 | c.5251C>A p.L1751I | Missense Mutation (SNP) | VAF 97/319 reads (30%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.202); catalogued as COSV50819008; called by muse, mutect2, varscan2
- ANKRD13A | c.1529C>T p.S510L | Missense Mutation (SNP) | VAF 94/362 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs756011134, COSV55675029; called by muse, mutect2, varscan2
- ANKRD13B | c.1117T>C p.W373R | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV61470074; called by muse, mutect2, varscan2
- ANKRD17 | c.3589A>C p.N1197H | Missense Mutation (SNP) | VAF 25/380 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100429843; called by muse, mutect2
- ANKRD2 | c.634C>T p.R212W | Missense Mutation (SNP) | VAF 31/108 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as rs539032791, COSV53967361; called by muse, mutect2, varscan2
- ANKRD24 | c.1893G>T p.E631D | Missense Mutation (SNP) | VAF 16/214 reads (7%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as COSV99518074; called by muse, mutect2
- ANKRD34B | c.575A>G p.K192R | Missense Mutation (SNP) | VAF 123/480 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV58613292; called by muse, mutect2, varscan2
- ANKRD50 | c.919G>T p.E307* | Nonsense Mutation (SNP) | VAF 57/189 reads (30%) | catalogued as COSV72385001; called by muse, mutect2, varscan2
- ANKRD7 | c.712+1G>A p.X238_splice | Splice Site (SNP) | VAF 144/526 reads (27%) | catalogued as rs113033396, COSV54556643; called by muse, mutect2, varscan2
- ANOS1 | c.494C>T p.S165L | Missense Mutation (SNP) | VAF 10/206 reads (5%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.937); catalogued as rs1404298787, COSV52916162; called by muse, mutect2
- ANP32D | c.61G>T p.E21* | Nonsense Mutation (SNP) | VAF 115/416 reads (28%) | catalogued as COSV56980026, COSV56980054, COSV56980118; called by muse, mutect2, varscan2
- ANXA1 | c.215G>A p.R72Q | Missense Mutation (SNP) | VAF 101/384 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs750091835, COSV57410292; called by muse, mutect2, varscan2
- AOC1 | c.1392T>G p.I464M | Missense Mutation (SNP) | VAF 35/111 reads (32%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.977); catalogued as COSV62866687; called by muse, mutect2, varscan2
- APC | c.6063C>A p.F2021L | Missense Mutation (SNP) | VAF 52/196 reads (27%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.992); catalogued as COSV57322456; called by muse, mutect2, varscan2
- APEX2 | c.187G>A p.V63I | Missense Mutation (SNP) | VAF 40/129 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.265); catalogued as rs745857862, COSV66623734; called by muse, mutect2, varscan2
- APEX2 | c.742C>T p.R248C | Missense Mutation (SNP) | VAF 25/96 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58188125; called by muse, mutect2, varscan2
- APLP1 | c.942G>T p.K314N | Missense Mutation (SNP) | VAF 62/206 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55701500; called by muse, mutect2, varscan2
- APLP1 | c.1020G>T p.K340N | Missense Mutation (SNP) | VAF 48/134 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.697); catalogued as COSV55701510; called by muse, mutect2, varscan2
- APOB | c.9306C>A p.F3102L | Missense Mutation (SNP) | VAF 63/256 reads (25%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.908); catalogued as COSV51922023; called by muse, mutect2, varscan2
- AR | c.2494C>T p.R832* | Nonsense Mutation (SNP) | VAF 23/312 reads (7%) | catalogued as CM920090, COSV65952973; called by muse, mutect2
- ARAF | c.127G>A p.D43N | Missense Mutation (SNP) | VAF 8/171 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.177); catalogued as rs1569319031, COSV51691372; called by muse, mutect2
- ARC | c.856C>A p.R286S | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.989); catalogued as rs988806388, COSV63077915, COSV63078032, COSV63078414; called by muse, mutect2
- ARG2 | c.821G>A p.R274Q | Missense Mutation (SNP) | VAF 50/215 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as rs371149374; called by muse, mutect2, varscan2
- ARGLU1 | c.622A>G p.N208D | Missense Mutation (SNP) | VAF 171/804 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as COSV62271220; called by muse, mutect2, varscan2
- ARHGAP15 | c.1285A>C p.S429R | Missense Mutation (SNP) | VAF 51/245 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); catalogued as COSV54475597; called by muse, mutect2, varscan2
- ARHGAP18 | c.1126C>A p.L376I | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.913); catalogued as COSV63763262, COSV63764002; called by muse, mutect2, varscan2
- ARHGAP21 | c.4324T>G p.F1442V | Missense Mutation (SNP) | VAF 101/324 reads (31%) | SIFT tolerated (0.44); PolyPhen benign (0.237); catalogued as COSV57601748; called by muse, mutect2, varscan2
- ARHGAP27 | c.1312C>T p.R438* (on ENST00000428638 / NM_001282290.1; = p.R97* on NM_199282.3) | Nonsense Mutation (SNP) | VAF 46/118 reads (39%) | catalogued as rs777988076, COSV65356991; called by muse, mutect2, varscan2
- ARHGEF12 | c.127G>T p.D43Y | Missense Mutation (SNP) | VAF 76/342 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV63102336; called by muse, mutect2, varscan2
- ARHGEF26 | c.1852C>T p.R618* | Nonsense Mutation (SNP) | VAF 25/504 reads (5%) | catalogued as rs772105688, COSV62853785; called by muse, mutect2
- ARID4A | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 47/238 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.012); catalogued as COSV62161852; called by muse, mutect2, varscan2
- ARID5B | c.735G>A p.A245= | Splice Region (SNP) | VAF 55/236 reads (23%) | catalogued as rs748749476, COSV54413474, COSV54421073; called by muse, mutect2, varscan2
- ARID5B | c.1366G>T p.E456* | Nonsense Mutation (SNP) | VAF 13/224 reads (6%) | catalogued as COSV54414410, COSV54415940; called by muse, mutect2
- ARID5B | c.2912C>T p.S971L | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs772815163, COSV54413484; called by muse, mutect2, varscan2
- ARIH1 | c.212G>A p.G71D | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0.023); catalogued as COSV65910220; called by muse, mutect2, varscan2
- ARIH2 | c.1171G>A p.E391K | Missense Mutation (SNP) | VAF 78/307 reads (25%) | SIFT tolerated (0.62); PolyPhen benign (0.041); catalogued as rs778218697, COSV62703753; called by muse, mutect2, varscan2
- ARMC2 | c.1041G>T p.K347N | Missense Mutation (SNP) | VAF 16/212 reads (8%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as rs1332449710, COSV100933645, COSV64552958; called by muse, mutect2
- ARMH3 | c.1255C>T p.R419* | Nonsense Mutation (SNP) | VAF 97/376 reads (26%) | catalogued as rs1383116155, COSV64232782; called by muse, mutect2, varscan2
- ARSI | c.574G>A p.D192N | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs746240121, COSV60816590; called by muse, mutect2, varscan2
- ASAH2 | c.65C>T p.A22V | Missense Mutation (SNP) | VAF 103/365 reads (28%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.007); catalogued as COSV61482693; called by muse, mutect2, varscan2
- ASB15 | c.1636C>T p.R546* | Nonsense Mutation (SNP) | VAF 37/163 reads (23%) | catalogued as rs1237485684, COSV51923543; called by muse, mutect2, varscan2
- ASCC3 | c.5759C>T p.A1920V | Missense Mutation (SNP) | VAF 91/406 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.728); catalogued as COSV64971914; called by muse, mutect2, varscan2
- ASL | c.66G>T p.E22D | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.029); catalogued as COSV59187855; called by muse, mutect2, varscan2
- ASPM | c.4504C>A p.Q1502K | Missense Mutation (SNP) | VAF 48/343 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.348); catalogued as COSV54124032; called by muse, mutect2, varscan2
- ASXL3 | c.5303G>T p.R1768I | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV52456258; called by muse, mutect2, varscan2
- ATAD2 | c.3214C>T p.R1072C | Missense Mutation (SNP) | VAF 15/183 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV54877785; called by muse, mutect2
- ATAD5 | c.3754G>T p.E1252* | Nonsense Mutation (SNP) | VAF 32/95 reads (34%) | catalogued as COSV58971756; called by muse, mutect2, varscan2
- ATE1 | c.1159G>T p.E387* | Nonsense Mutation (SNP) | VAF 8/102 reads (8%) | catalogued as COSV56435876, COSV99817607; called by muse, mutect2
- ATF7IP2 | c.584A>G p.D195G | Missense Mutation (SNP) | VAF 15/282 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.085); catalogued as COSV100202745; called by muse, mutect2
- ATF7IP2 | c.1379C>T p.S460F | Missense Mutation (SNP) | VAF 102/339 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61092065; called by muse, mutect2, varscan2
- ATP10A | c.523G>A p.E175K | Missense Mutation (SNP) | VAF 37/219 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.846); catalogued as COSV63512994; called by muse, mutect2, varscan2
- ATP10D | c.1466C>A p.S489Y | Missense Mutation (SNP) | VAF 62/207 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.078); catalogued as COSV56703393; called by muse, mutect2, varscan2
- ATP13A5 | c.2690C>T p.A897V | Missense Mutation (SNP) | VAF 23/203 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV60865276; called by muse, mutect2, varscan2
- ATP1B1 | c.740G>A p.G247D | Missense Mutation (SNP) | VAF 63/289 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV63164617; called by muse, mutect2, varscan2
- ATP1B4 | c.684G>T p.K228N (on ENST00000218008 / NM_001142447.3; = p.K224N on NM_012069.5) | Missense Mutation (SNP) | VAF 79/298 reads (27%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.702); catalogued as COSV54311044; called by muse, mutect2, varscan2
- ATP6V1B1 | c.991C>T p.R331W | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs982193032, COSV52268095; called by muse, mutect2, varscan2
- ATP6V1B2 | c.922C>T p.R308* | Nonsense Mutation (SNP) | VAF 80/254 reads (31%) | catalogued as rs777139485, COSV52352683; called by muse, mutect2, varscan2
- ATP7B | c.2281G>T p.V761L | Missense Mutation (SNP) | VAF 29/111 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0.019); catalogued as COSV54434840; called by muse, mutect2, varscan2
- ATP8A1 | c.1129G>T p.D377Y | Missense Mutation (SNP) | VAF 14/308 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100046102, COSV52540882; called by muse, mutect2
- ATRX | c.1821A>C p.E607D | Missense Mutation (SNP) | VAF 38/147 reads (26%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.003); catalogued as COSV64870850; called by muse, mutect2, varscan2
- AUH | c.499G>A p.D167N | Missense Mutation (SNP) | VAF 97/330 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as rs776409546, COSV57861320; called by muse, mutect2, varscan2
- AVEN | c.306G>T p.E102D | Missense Mutation (SNP) | VAF 94/350 reads (27%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.946); catalogued as COSV60732032; called by muse, mutect2, varscan2
- B4GAT1 | c.781G>A p.E261K | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60819620; called by muse, mutect2, varscan2
- BAK1 | c.478G>A p.D160N | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.083); catalogued as rs1417013867, COSV62349247, COSV62349385; called by muse, mutect2, varscan2
- BARX1 | c.506C>T p.T169M | Missense Mutation (SNP) | VAF 19/101 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs750149824, COSV54158665; called by muse, mutect2, varscan2
- BAZ1B | c.1126A>G p.N376D | Missense Mutation (SNP) | VAF 64/434 reads (15%) | SIFT tolerated (0.63); PolyPhen benign (0.011); catalogued as rs782748669, COSV59988300; called by muse, mutect2, varscan2
- BAZ2B | c.3269T>G p.F1090C | Missense Mutation (SNP) | VAF 44/169 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV54274773; called by muse, mutect2, varscan2
- BBS5 | c.934C>T p.R312C | Missense Mutation (SNP) | VAF 113/387 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV54751728; called by muse, mutect2, varscan2
- BCHE | c.1355G>A p.R452Q | Missense Mutation (SNP) | VAF 63/191 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.12); catalogued as COSV100012005, COSV52253121; called by muse, mutect2, varscan2
- BCL11B | c.417G>T p.E139D | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV61732974; called by muse, mutect2, varscan2
- BCOR | c.4214C>T p.S1405L (on ENST00000378444 / NM_001123385.2; = p.S1371L on NM_017745.6) | Missense Mutation (SNP) | VAF 47/173 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.014); catalogued as COSV60698832, COSV60710046; called by muse, mutect2, varscan2
- BCORL1 | c.4981G>A p.A1661T | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.158); catalogued as COSV54396103, COSV99500669; called by muse, mutect2
- BDP1 | c.7349G>T p.R2450I | Missense Mutation (SNP) | VAF 53/253 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as rs544031248, COSV62428641; called by muse, mutect2, varscan2
- BEND6 | c.814A>C p.N272H | Missense Mutation (SNP) | VAF 69/254 reads (27%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.188); catalogued as COSV66067862; called by muse, mutect2, varscan2
- BEX1 | c.317G>A p.R106Q | Missense Mutation (SNP) | VAF 144/480 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.04); catalogued as rs781240940, COSV65579609; called by muse, mutect2, varscan2
- BEX3 | c.106C>T p.R36* | Nonsense Mutation (SNP) | VAF 92/314 reads (29%) | catalogued as COSV55420975; called by muse, mutect2, varscan2
- BFSP1 | c.1193A>C p.K398T | Missense Mutation (SNP) | VAF 149/480 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.05); catalogued as COSV104428533, COSV64899219; called by muse, mutect2, varscan2
- BMP15 | c.197C>A p.S66* | Nonsense Mutation (SNP) | VAF 30/95 reads (32%) | catalogued as COSV53139804; called by muse, mutect2, varscan2
- BMP15 | c.640G>T p.D214Y | Missense Mutation (SNP) | VAF 69/302 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.171); catalogued as COSV53139815; called by muse, mutect2, varscan2
- BMP7 | c.517G>A p.E173K | Missense Mutation (SNP) | VAF 37/152 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV67779434; called by muse, mutect2, varscan2
- BMX | c.1371C>A p.F457L | Missense Mutation (SNP) | VAF 142/483 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs754428384, COSV59590089; called by muse, varscan2
- BNC2 | c.2740G>A p.D914N | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (0.19); PolyPhen benign (0.105); catalogued as rs1385446031, COSV66160377; called by muse, mutect2, varscan2
- BNIP5 | c.92C>T p.S31L | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.017); catalogued as rs777896318, COSV71325269; called by muse, mutect2, varscan2
- BOLL | c.19T>G p.S7A | Missense Mutation (SNP) | VAF 144/598 reads (24%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.661); catalogued as COSV56572963; called by muse, mutect2, varscan2
- BRCA1 | c.1932T>G p.C644W | Missense Mutation (SNP) | VAF 34/170 reads (20%) | SIFT tolerated (0.28); PolyPhen benign (0.111); catalogued as rs397508918, CM995147, COSV58783577; ClinVar: not provided; called by muse, mutect2, varscan2
- BRD8 | c.1177G>T p.E393* (on ENST00000254900 / NM_139199.2; = p.E466* on NM_006696.4) | Nonsense Mutation (SNP) | VAF 75/326 reads (23%) | catalogued as COSV50145045; called by muse, mutect2, varscan2
- BRDT | c.1384G>T p.E462* | Nonsense Mutation (SNP) | VAF 50/190 reads (26%) | catalogued as COSV100746348, COSV62863070; called by muse, mutect2, varscan2
- BRIX1 | c.547G>A p.E183K | Missense Mutation (SNP) | VAF 93/475 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.775); catalogued as COSV59130663; called by muse, mutect2, varscan2
- C11orf53 | c.722C>T p.T241M | Missense Mutation (SNP) | VAF 56/167 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.606); catalogued as rs370946784; called by muse, mutect2, varscan2
- C12orf4 | c.1004G>A p.R335Q | Missense Mutation (SNP) | VAF 60/249 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as rs532268400, COSV54205508; called by muse, mutect2, varscan2
- C14orf39 | c.104A>C p.N35T | Missense Mutation (SNP) | VAF 92/306 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.778); catalogued as COSV58779233; called by muse, mutect2, varscan2
- C16orf70 | c.293C>A p.S98Y | Missense Mutation (SNP) | VAF 33/188 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs776122798, COSV54625397, COSV54627728; called by muse, mutect2, varscan2
- C18orf54 | c.498G>T p.K166N | Missense Mutation (SNP) | VAF 33/198 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.01); catalogued as COSV55617189; called by muse, mutect2, varscan2
- C1orf141 | c.957G>T p.Q319H | Missense Mutation (SNP) | VAF 50/194 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.967); catalogued as COSV63992007; called by muse, mutect2, varscan2
- C1orf146 | c.234G>T p.E78D | Missense Mutation (SNP) | VAF 35/134 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.109); catalogued as COSV64859816; called by muse, mutect2, varscan2
- C22orf23 | c.283C>T p.R95W | Missense Mutation (SNP) | VAF 35/212 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs199929592, COSV50777620; called by muse, mutect2, varscan2
- C2CD5 | c.2853G>T p.E951D | Missense Mutation (SNP) | VAF 88/331 reads (27%) | SIFT tolerated (0.75); PolyPhen benign (0.069); catalogued as rs1340410416, COSV61722508, COSV61727705; called by muse, mutect2, varscan2
- C2CD5 | c.1150G>T p.E384* | Nonsense Mutation (SNP) | VAF 129/484 reads (27%) | catalogued as COSV61722518; called by muse, mutect2, varscan2
- C2orf16 | c.426A>C p.Q142H | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.875); catalogued as rs1157038931, COSV68645309; called by muse, mutect2, varscan2
- C3orf52 | c.271A>C p.T91P | Missense Mutation (SNP) | VAF 64/367 reads (17%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.839); catalogued as COSV53494585; called by muse, mutect2, varscan2
- C3orf62 | c.554G>A p.R185Q | Missense Mutation (SNP) | VAF 26/115 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.077); catalogued as rs770343603, COSV57985227; called by muse, mutect2, varscan2
- C4BPA | c.1342G>T p.E448* | Nonsense Mutation (SNP) | VAF 76/343 reads (22%) | catalogued as rs1215951903, COSV65535588; called by muse, mutect2, varscan2
- C7 | c.1000G>T p.E334* | Nonsense Mutation (SNP) | VAF 72/311 reads (23%) | catalogued as COSV57470260; called by muse, mutect2, varscan2
- C9 | c.1163C>A p.S388Y | Missense Mutation (SNP) | VAF 32/520 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV99662445; called by muse, mutect2
- C9 | c.358A>C p.N120H | Missense Mutation (SNP) | VAF 47/171 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54674020; called by muse, mutect2, varscan2
- CABP1 | c.858C>A p.F286L (on ENST00000316803 / NM_001033677.1; = p.F83L on NM_004276.5) | Missense Mutation (SNP) | VAF 22/478 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); catalogued as COSV56457881, COSV56458534; called by muse, mutect2
- CACNA1C | c.2129C>T p.S710L | Missense Mutation (SNP) | VAF 106/387 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as COSV59695046; called by muse, mutect2, varscan2
- CACNA1E | c.4178G>A p.R1393H | Missense Mutation (SNP) | VAF 137/446 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.273); catalogued as rs760283783, COSV62381281; called by muse, mutect2, varscan2
- CACNA1H | c.4754G>A p.R1585H | Missense Mutation (SNP) | VAF 41/124 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.955); catalogued as rs774569737, COSV61982966; called by muse, mutect2, varscan2
- CACNA1S | c.2764T>C p.F922L | Missense Mutation (SNP) | VAF 14/103 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1211786403, COSV62938290; called by muse, mutect2
- CACNA2D2 | c.1264C>T p.R422C | Missense Mutation (SNP) | VAF 33/116 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56560122; called by muse, mutect2, varscan2
- CACNA2D3 | c.868G>T p.D290Y | Missense Mutation (SNP) | VAF 94/359 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55510849; called by muse, mutect2, varscan2
- CACNB3 | c.218T>C p.V73A | Missense Mutation (SNP) | VAF 38/161 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56396984; called by muse, mutect2, varscan2
- CACNG8 | c.478C>A p.L160M | Missense Mutation (SNP) | VAF 36/161 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54413588; called by muse, varscan2
- CADPS | c.841C>A p.L281I | Missense Mutation (SNP) | VAF 35/84 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as COSV51865833; called by muse, mutect2, varscan2
- CADPS2 | c.3736C>T p.R1246* | Nonsense Mutation (SNP) | VAF 11/341 reads (3%) | catalogued as rs1354028382, COSV57349948, COSV57350326; called by muse, mutect2
- CALCOCO1 | c.410C>G p.S137C | Missense Mutation (SNP) | VAF 28/96 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.921); catalogued as rs1286159760, COSV50411599; called by muse, mutect2, varscan2
- CALM2 | c.345G>T p.E115D | Missense Mutation (SNP) | VAF 24/740 reads (3%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.337); catalogued as COSV99700981; called by muse, mutect2
- CALN1 | c.82G>A p.E28K (on ENST00000329008 / NM_001017440.3; = p.E70K on NM_031468.4) | Missense Mutation (SNP) | VAF 27/104 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.017); catalogued as rs969416503, COSV61118054; called by muse, mutect2, varscan2
- CAMK1D | c.237A>C p.E79D | Missense Mutation (SNP) | VAF 115/505 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.161); catalogued as COSV66606192; called by muse, mutect2, varscan2
- CAMTA1 | c.3421G>A p.D1141N | Missense Mutation (SNP) | VAF 28/121 reads (23%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.993); catalogued as rs755334866, COSV57880097; called by muse, mutect2, varscan2
- CAMTA1 | c.4400C>A p.S1467Y | Missense Mutation (SNP) | VAF 10/160 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.541); catalogued as COSV100352110; called by muse, mutect2
- CAP2 | c.401C>T p.S134L | Missense Mutation (SNP) | VAF 70/251 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200559179, COSV57729499; called by muse, mutect2, varscan2
- CAPN10 | c.242C>T p.A81V | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.67); catalogued as rs745593937, COSV54374694; called by muse, mutect2, varscan2
- CAPZA3 | c.46C>T p.R16C | Missense Mutation (SNP) | VAF 16/132 reads (12%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs777052411, COSV56848439; called by muse, mutect2, varscan2
- CASP4 | c.531G>T p.E177D | Missense Mutation (SNP) | VAF 14/388 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.141); catalogued as COSV101274200; called by muse, mutect2
- CASP8 | c.14G>T p.R5I | Missense Mutation (SNP) | VAF 26/123 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.034); catalogued as COSV51844956; called by muse, mutect2, varscan2
- CASP8AP2 | c.758G>A p.S253N | Missense Mutation (SNP) | VAF 57/231 reads (25%) | SIFT tolerated (0.48); PolyPhen benign (0.006); catalogued as rs1258383336, COSV99387467; called by muse, mutect2, varscan2
- CASS4 | c.976G>T p.D326Y | Missense Mutation (SNP) | VAF 28/127 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.188); catalogued as rs140450802; called by muse, mutect2, varscan2
- CAST | c.1557C>A p.F519L (on ENST00000341926; = p.F602L on NM_001750.7 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 113/396 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV57085004; called by muse, mutect2, varscan2
- CATSPERB | c.1012C>A p.L338I | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs754792783, COSV56421740; called by muse, mutect2, varscan2
- CAVIN1 | c.179A>C p.K60T | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63811321; called by muse, mutect2, varscan2
- CBFA2T3 | c.307C>T p.R103* | Nonsense Mutation (SNP) | VAF 57/219 reads (26%) | catalogued as COSV51922710; called by muse, mutect2, varscan2
- CBL | c.965A>C p.K322T | Missense Mutation (SNP) | VAF 99/464 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV50629702; called by muse, mutect2, varscan2
- CBLL1 | c.74G>A p.R25Q | Missense Mutation (SNP) | VAF 94/377 reads (25%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.061); catalogued as rs756843724, COSV56027915, COSV56028047; called by muse, mutect2, varscan2
- CCAR1 | c.1645C>T p.R549C | Missense Mutation (SNP) | VAF 57/308 reads (19%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.998); catalogued as COSV56266888; called by muse, mutect2, varscan2
- CCDC110 | c.1903G>T p.E635* | Nonsense Mutation (SNP) | VAF 72/266 reads (27%) | catalogued as COSV56869160; called by muse, mutect2, varscan2
- CCDC138 | c.829G>T p.E277* | Nonsense Mutation (SNP) | VAF 29/166 reads (17%) | catalogued as rs752809632, COSV54564084; called by muse, mutect2, varscan2
- CCDC144A | c.1355A>C p.K452T | Missense Mutation (SNP) | VAF 180/481 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.063); catalogued as COSV60695873; called by muse, mutect2, varscan2
- CCDC146 | c.1465G>A p.E489K | Missense Mutation (SNP) | VAF 84/326 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.793); catalogued as COSV53543643, COSV53551611; called by muse, mutect2, varscan2
- CCDC15 | c.490G>A p.E164K | Missense Mutation (SNP) | VAF 59/224 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.373); catalogued as rs201773360; called by muse, mutect2, varscan2
- CCDC180 | c.4120G>A p.E1374K | Missense Mutation (SNP) | VAF 20/175 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as rs988355859, COSV63826472; called by muse, mutect2, varscan2
- CCDC73 | c.2532G>T p.E844D | Missense Mutation (SNP) | VAF 75/274 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.192); catalogued as COSV58794889; called by muse, mutect2, varscan2
- CCDC73 | c.352G>T p.E118* | Nonsense Mutation (SNP) | VAF 170/753 reads (23%) | catalogued as rs1370064416, COSV58794903, COSV58797375; called by muse, mutect2, varscan2
- CCDC82 | c.83G>A p.R28Q | Missense Mutation (SNP) | VAF 91/433 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs753336168, COSV53591996; called by muse, mutect2, varscan2
- CCDC85A | c.1619T>G p.I540S | Missense Mutation (SNP) | VAF 93/364 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV68147281; called by muse, mutect2, varscan2
- CCDC87 | c.854C>T p.S285L | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs141059944; called by muse, mutect2, varscan2
- CCDC88B | c.1292A>G p.E431G | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.871); catalogued as COSV57264787; called by muse, mutect2, varscan2
- CCN1 | c.643A>T p.M215L | Missense Mutation (SNP) | VAF 73/286 reads (26%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV71704257; called by muse, mutect2, varscan2
- CCNB3 | c.678G>T p.K226N | Missense Mutation (SNP) | VAF 25/109 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.006); catalogued as rs782639340, COSV52069526; called by muse, mutect2, varscan2
- CCP110 | c.1048G>A p.E350K | Missense Mutation (SNP) | VAF 22/104 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.886); catalogued as rs768611357, COSV101195326; called by muse, mutect2
- CCP110 | c.2393A>C p.K798T | Missense Mutation (SNP) | VAF 23/592 reads (4%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); catalogued as COSV101195327; called by muse, mutect2
- CCR2 | c.83A>G p.Y28C | Missense Mutation (SNP) | VAF 78/296 reads (26%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.593); catalogued as COSV52747520; called by muse, mutect2, varscan2
- CCT6B | c.797T>G p.F266C | Missense Mutation (SNP) | VAF 110/289 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as rs1392813706, COSV58487686; called by muse, mutect2, varscan2
- CCZ1B | c.165G>T p.K55N | Missense Mutation (SNP) | VAF 98/689 reads (14%) | SIFT tolerated (0.49); PolyPhen benign (0.234); catalogued as COSV57435894; called by muse, mutect2, varscan2
- CD109 | c.3865G>T p.E1289* | Nonsense Mutation (SNP) | VAF 60/315 reads (19%) | catalogued as COSV54644838; called by muse, mutect2, varscan2
- CD14 | c.910C>A p.L304I | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as COSV57369765; called by muse, mutect2, varscan2
- CD180 | c.1616C>A p.S539Y | Missense Mutation (SNP) | VAF 20/94 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.531); catalogued as COSV56516673, COSV99842027; called by muse, mutect2, varscan2
- CDC25B | c.1467C>A p.F489L (on ENST00000245960 / NM_021873.3; = p.F475L on NM_004358.4) | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1399244459, COSV55654341; called by muse, mutect2, varscan2
- CDC7 | c.443C>A p.S148Y | Missense Mutation (SNP) | VAF 125/463 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs375702482, COSV52309241, COSV99319834; called by muse, mutect2, varscan2
- CDCA2 | c.2818G>T p.E940* | Nonsense Mutation (SNP) | VAF 55/156 reads (35%) | catalogued as COSV57944091; called by muse, mutect2, varscan2
- CDH17 | c.1040T>G p.F347C | Missense Mutation (SNP) | VAF 81/329 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.272); catalogued as COSV50325488; called by muse, mutect2, varscan2
- CDH6 | c.1399A>G p.K467E | Missense Mutation (SNP) | VAF 25/143 reads (17%) | SIFT tolerated (0.63); PolyPhen benign (0.14); catalogued as COSV54063514; called by muse, mutect2, varscan2
- CDH8 | c.577G>A p.D193N | Missense Mutation (SNP) | VAF 41/188 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV104408049, COSV54845838; called by muse, mutect2, varscan2
- CDHR3 | c.1382T>G p.F461C | Missense Mutation (SNP) | VAF 18/419 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100488789; called by muse, mutect2
- CDKN2AIP | c.334G>A p.A112T | Missense Mutation (SNP) | VAF 16/240 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100187705; called by muse, mutect2
- CEACAM3 | c.440G>T p.G147V | Missense Mutation (SNP) | VAF 32/131 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.312); catalogued as COSV55760643, COSV99705113; called by muse, mutect2, varscan2
- CEACAM5 | c.625G>A p.D209N | Missense Mutation (SNP) | VAF 71/294 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV55750407; called by muse, mutect2, varscan2
- CELA3A | c.680A>G p.D227G | Missense Mutation (SNP) | VAF 34/106 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.027); catalogued as COSV51581829; called by muse, mutect2, varscan2
- CELF3 | c.1349G>A p.R450H | Missense Mutation (SNP) | VAF 28/110 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1438468226, COSV51881375; called by muse, mutect2, varscan2
- CEMIP2 | c.1815C>A p.F605L | Missense Mutation (SNP) | VAF 63/322 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.474); catalogued as COSV65485422; called by muse, mutect2, varscan2
- CENPE | c.376C>A p.L126I | Missense Mutation (SNP) | VAF 67/199 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54375625; called by muse, mutect2, varscan2
- CENPF | c.701G>T p.R234I | Missense Mutation (SNP) | VAF 39/201 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.077); catalogued as COSV65272425; called by muse, mutect2, varscan2
- CENPI | c.1827-1G>T p.X609_splice | Splice Site (SNP) | VAF 58/325 reads (18%) | catalogued as COSV54500400; called by muse, mutect2, varscan2
- CEP112 | c.700A>G p.K234E | Missense Mutation (SNP) | VAF 37/266 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.51); catalogued as COSV67135728; called by muse, mutect2, varscan2
- CEP290 | c.3134A>C p.K1045T | Missense Mutation (SNP) | VAF 48/180 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV58348271; called by muse, mutect2, varscan2
- CEP78 | c.966G>T p.W322C | Missense Mutation (SNP) | VAF 119/460 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.241); catalogued as COSV52845293; called by muse, varscan2
- CEP78 | c.1051A>C p.K351Q | Missense Mutation (SNP) | VAF 78/292 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV52845313; called by muse, varscan2
- CERS3 | c.1060G>T p.E354* | Nonsense Mutation (SNP) | VAF 84/317 reads (26%) | catalogued as rs1392551498, COSV52564430; called by muse, mutect2, varscan2
- CERS5 | c.632G>T p.R211I | Missense Mutation (SNP) | VAF 93/366 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58188192; called by muse, mutect2, varscan2
- CERS6 | c.56T>C p.V19A | Missense Mutation (SNP) | VAF 44/174 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.725); catalogued as COSV59826098; called by muse, mutect2, varscan2
- CFAP43 | c.2738G>A p.R913H | Missense Mutation (SNP) | VAF 35/572 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs755312187, COSV99530965; called by muse, mutect2
- CFAP58 | c.828A>C p.Q276H | Missense Mutation (SNP) | VAF 117/255 reads (46%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.717); catalogued as COSV57211172; called by muse, mutect2, varscan2
- CFAP69 | c.216G>T p.K72N | Missense Mutation (SNP) | VAF 67/285 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.168); catalogued as COSV100290018, COSV60184021; called by muse, mutect2, varscan2
- CHD2 | c.5417G>A p.R1806K | Missense Mutation (SNP) | VAF 42/412 reads (10%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.931); catalogued as COSV101244879, COSV101245870; called by muse, mutect2
- CHD3 | c.5159A>G p.H1720R (on ENST00000330494 / NM_001005273.3; = p.H1686R on NM_005852.4) | Missense Mutation (SNP) | VAF 51/178 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.613); catalogued as COSV57872253; called by muse, mutect2, varscan2
- CHD4 | c.3605T>G p.L1202R (on ENST00000357008 / NM_001363606.2; = p.L1215R on NM_001273.5) | Missense Mutation (SNP) | VAF 43/149 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58894301, COSV58894430; called by muse, mutect2, varscan2
- CHD5 | c.5858A>C p.D1953A | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT tolerated, low confidence (0.13); PolyPhen probably damaging (0.968); catalogued as COSV52407056, COSV52421292; called by muse, mutect2, varscan2
- CHD9 | c.218A>G p.Q73R | Missense Mutation (SNP) | VAF 71/240 reads (30%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.075); catalogued as COSV68296927; called by muse, mutect2, varscan2
- CHI3L1 | c.595G>A p.D199N | Missense Mutation (SNP) | VAF 40/198 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55136989; called by muse, mutect2, varscan2
- CHMP3 | c.201G>T p.M67I | Missense Mutation (SNP) | VAF 17/408 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99806803; called by muse, mutect2
- CHRNA1 | c.1087G>A p.D363N (on ENST00000261007 / NM_001039523.3; = p.D338N on NM_000079.4) | Missense Mutation (SNP) | VAF 74/264 reads (28%) | SIFT tolerated (0.36); PolyPhen benign (0.009); catalogued as COSV53681480; called by muse, mutect2, varscan2
- CHRNB3 | c.349C>A p.L117I | Missense Mutation (SNP) | VAF 41/217 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV51492976; called by muse, mutect2, varscan2
- CIT | c.2833G>A p.V945I | Missense Mutation (SNP) | VAF 66/389 reads (17%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.956); catalogued as COSV55859105; called by muse, mutect2, varscan2
- CLASP1 | c.1057T>G p.L353V | Missense Mutation (SNP) | VAF 54/205 reads (26%) | SIFT tolerated (0.64); PolyPhen possibly damaging (0.688); catalogued as COSV55312484; called by muse, mutect2, varscan2
- CLASP1 | c.641C>T p.S214F | Missense Mutation (SNP) | VAF 104/389 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.646); catalogued as COSV55312535; called by muse, mutect2, varscan2
- CLCN1 | c.199G>T p.E67* | Nonsense Mutation (SNP) | VAF 74/267 reads (28%) | catalogued as CM076098, COSV58367166; called by muse, mutect2, varscan2
- CLCN3 | c.587T>G p.L196* | Nonsense Mutation (SNP) | VAF 84/308 reads (27%) | catalogued as COSV61626167; called by muse, mutect2, varscan2
- CLCN3 | c.1939G>T p.E647* | Nonsense Mutation (SNP) | VAF 92/339 reads (27%) | catalogued as rs1189153280, COSV61626171; called by muse, mutect2, varscan2
- CLCN6 | c.1725T>G p.I575M | Missense Mutation (SNP) | VAF 30/255 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.83); catalogued as COSV56737753; called by muse, mutect2, varscan2
- CLDN19 | c.626+1G>A p.X209_splice | Splice Site (SNP) | VAF 17/47 reads (36%) | catalogued as rs774289795, COSV56417028; called by muse, mutect2, varscan2
- CLDN20 | c.467A>G p.N156S | Missense Mutation (SNP) | VAF 25/130 reads (19%) | SIFT tolerated (0.64); PolyPhen benign (0.019); catalogued as rs1436649813, COSV65696943; called by muse, mutect2, varscan2
- CLEC10A | c.380C>T p.T127M | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as rs376732406; called by muse, mutect2, varscan2
- CLEC5A | c.231T>G p.F77L | Missense Mutation (SNP) | VAF 80/346 reads (23%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV69396681; called by muse, mutect2, varscan2
- CLHC1 | c.1621G>T p.E541* | Nonsense Mutation (SNP) | VAF 110/366 reads (30%) | catalogued as COSV68463456; called by muse, varscan2
- CLHC1 | c.286C>A p.H96N | Missense Mutation (SNP) | VAF 102/469 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.417); catalogued as rs759727366, COSV63427045; called by muse, mutect2, varscan2
- CLIP1 | c.1705G>T p.E569* (on ENST00000620786 / NM_001247997.1; = p.E558* on NM_002956.2) | Nonsense Mutation (SNP) | VAF 32/126 reads (25%) | catalogued as COSV56796871, COSV56801808; called by muse, mutect2, varscan2
- CLSPN | c.512G>T p.R171I | Missense Mutation (SNP) | VAF 22/565 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52048818; called by muse, mutect2
- CLTC | c.2237G>T p.R746I | Missense Mutation (SNP) | VAF 144/356 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as COSV52244572; called by muse, mutect2, varscan2
- CMYA5 | c.6628G>A p.V2210I | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.026); catalogued as rs751513243, COSV71404031; called by muse, mutect2, varscan2
- CMYA5 | c.8896G>A p.D2966N | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs959129009, COSV71404032; called by muse, mutect2, varscan2
- CNBD2 | c.1630C>T p.R544C (on ENST00000373973 / NM_001365709.1; = p.R540C on NM_080834.4) | Missense Mutation (SNP) | VAF 80/332 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs757298997, COSV62586275; called by muse, mutect2, varscan2
- CNMD | c.364G>T p.G122* | Nonsense Mutation (SNP) | VAF 49/247 reads (20%) | catalogued as COSV65032256; called by muse, mutect2, varscan2
- CNMD | c.351G>T p.Q117H | Missense Mutation (SNP) | VAF 20/426 reads (5%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.88); catalogued as COSV100937316; called by muse, mutect2
- CNN3 | c.51G>T p.K17N | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV64636523; called by muse, mutect2, varscan2
- CNOT1 | c.5198G>A p.R1733H | Missense Mutation (SNP) | VAF 86/313 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.241); catalogued as rs185344213, COSV55312634; called by muse, mutect2, varscan2
- CNOT1 | c.1163A>G p.E388G | Missense Mutation (SNP) | VAF 106/408 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.253); catalogued as COSV57763686; called by muse, mutect2, varscan2
- CNOT3 | c.14G>A p.R5H | Missense Mutation (SNP) | VAF 16/290 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55368995; called by muse, mutect2
- CNPY1 | c.61G>A p.A21T | Missense Mutation (SNP) | VAF 25/129 reads (19%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.742); catalogued as rs1344924963, COSV58786479; called by muse, mutect2, varscan2
- CNR1 | c.892C>A p.L298I | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62986328; called by muse, mutect2, varscan2
- CNST | c.1393C>T p.R465W | Missense Mutation (SNP) | VAF 32/118 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs774267182, COSV63621423; called by muse, mutect2, varscan2
- CNTLN | c.2511C>G p.C837W | Missense Mutation (SNP) | VAF 42/166 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.852); catalogued as COSV52065024; called by muse, mutect2, varscan2
- CNTN2 | c.2970_2971insT p.G991Wfs*89 | Frame Shift Ins (INS) | VAF 12/68 reads (18%) | catalogued as COSV100085394; called by mutect2, pindel, varscan2
- CNTNAP4 | c.1195C>T p.R399* | Nonsense Mutation (SNP) | VAF 68/257 reads (26%) | catalogued as COSV56662760; called by muse, mutect2
- COG3 | c.625-1G>T p.X209_splice | Splice Site (SNP) | VAF 63/274 reads (23%) | catalogued as COSV63071148; called by muse, mutect2, varscan2
- COL14A1 | c.655G>T p.D219Y | Missense Mutation (SNP) | VAF 95/343 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.934); catalogued as COSV52846531; called by muse, mutect2, varscan2
- COL17A1 | c.3403C>A p.L1135I | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT tolerated (0.51); PolyPhen benign (0.005); catalogued as COSV62225064; called by muse, mutect2, varscan2
- COL19A1 | c.1185A>G p.I395M | Missense Mutation (SNP) | VAF 96/416 reads (23%) | SIFT tolerated (0.26); PolyPhen benign (0.009); catalogued as COSV59564508; called by muse, mutect2, varscan2
- COL25A1 | c.273G>T p.E91D | Missense Mutation (SNP) | VAF 51/220 reads (23%) | SIFT tolerated (0.48); PolyPhen benign (0.001); catalogued as rs372608218; called by muse, mutect2, varscan2
- COL28A1 | c.683A>C p.D228A | Missense Mutation (SNP) | VAF 88/323 reads (27%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as COSV68080361; called by muse, mutect2, varscan2
- COL6A3 | c.2714G>T p.R905I | Missense Mutation (SNP) | VAF 7/107 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.5); catalogued as COSV99800776; called by muse, mutect2
- COMP | c.506C>T p.A169V | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.035); catalogued as rs758276062, COSV55873662; called by muse, mutect2, varscan2
- COPS4 | c.247G>T p.E83* | Nonsense Mutation (SNP) | VAF 17/324 reads (5%) | catalogued as COSV100018798; called by muse, mutect2
- CP | c.3079G>T p.E1027* | Nonsense Mutation (SNP) | VAF 76/319 reads (24%) | catalogued as COSV52828890; called by muse, mutect2, varscan2
- CP | c.2758T>C p.F920L | Missense Mutation (SNP) | VAF 88/423 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs754403684, COSV52828897; called by muse, mutect2, varscan2
- CPA4 | c.1102G>A p.D368N | Missense Mutation (SNP) | VAF 18/210 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs751952099, COSV55985056; called by muse, mutect2
- CPE | c.776A>G p.D259G | Missense Mutation (SNP) | VAF 46/538 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV101291683; called by muse, mutect2
- CPEB4 | c.1055G>A p.S352N | Missense Mutation (SNP) | VAF 31/142 reads (22%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); catalogued as COSV54169166; called by muse, mutect2, varscan2
- CPN1 | c.265G>A p.E89K | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752224544, COSV64941882; called by muse, mutect2, varscan2
- CPO | c.28C>A p.L10I | Missense Mutation (SNP) | VAF 24/849 reads (3%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.018); catalogued as COSV55938754, COSV99786621; called by muse, mutect2
- CR1 | c.2342A>G p.D781G | Missense Mutation (SNP) | VAF 26/442 reads (6%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.981); catalogued as COSV100887988; called by muse, mutect2
- CR1 | c.2701G>A p.D901N | Missense Mutation (SNP) | VAF 103/801 reads (13%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.988); catalogued as rs571845275, COSV65455567, COSV65463610; called by muse, mutect2, varscan2
- CRB1 | c.1976C>T p.S659L | Missense Mutation (SNP) | VAF 60/194 reads (31%) | SIFT tolerated (0.22); PolyPhen benign (0.014); catalogued as rs986645649, COSV66328552; called by muse, mutect2, varscan2
- CREB1 | c.901C>T p.R301C (on ENST00000432329 / NM_134442.5; = p.R287C on NM_004379.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 47/183 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62063612; called by muse, mutect2, varscan2
- CREBBP | c.6310C>T p.R2104C | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1489860615, COSV52112713; called by muse, mutect2, varscan2
- CRYBA4 | c.569G>A p.S190N | Missense Mutation (SNP) | VAF 26/110 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100697718, COSV61321256; called by muse, mutect2, varscan2
- CRYBG1 | c.4831C>T p.R1611W | Missense Mutation (SNP) | VAF 65/216 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs373859652; called by muse, mutect2, varscan2
- CRYBG1 | c.6001C>T p.R2001* | Nonsense Mutation (SNP) | VAF 53/289 reads (18%) | catalogued as rs905650846, COSV64810402; called by muse, mutect2, varscan2
- CSDE1 | c.2320C>T p.R774C (on ENST00000358528 / NM_001007553.3; = p.R743C on NM_007158.6) | Missense Mutation (SNP) | VAF 56/262 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); catalogued as COSV54737056; called by muse, mutect2, varscan2
- CSMD1 | c.10375G>T p.D3459Y (on ENST00000520002; = p.D3458Y on NM_033225.6) | Missense Mutation (SNP) | VAF 85/391 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as COSV59278090, COSV59387173; called by muse, mutect2, varscan2
- CSMD1 | c.6209C>T p.S2070L (on ENST00000520002; = p.S2069L on NM_033225.6) | Missense Mutation (SNP) | VAF 68/270 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs755657382, COSV59278108; called by muse, mutect2, varscan2
- CSMD1 | c.4627C>T p.R1543W (on ENST00000520002; = p.R1542W on NM_033225.6) | Missense Mutation (SNP) | VAF 29/178 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV59278132; called by muse, mutect2, varscan2
- CSMD3 | c.6691C>T p.R2231* (on ENST00000297405 / NM_001363185.1; = p.R2127* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 57/223 reads (26%) | catalogued as rs751474008, COSV52093601, COSV52154452; called by muse, mutect2, varscan2
- CSMD3 | c.3427C>T p.P1143S (on ENST00000297405 / NM_001363185.1; = p.P1039S on NM_052900.3) | Missense Mutation (SNP) | VAF 62/268 reads (23%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV52093613; called by muse, mutect2, varscan2
- CSMD3 | c.2776G>T p.E926* (on ENST00000297405 / NM_001363185.1; = p.E822* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 85/266 reads (32%) | catalogued as rs763942016, COSV52093629, COSV99848390; called by muse, mutect2, varscan2
- CSMD3 | c.2041T>C p.S681P (on ENST00000297405 / NM_001363185.1; = p.S577P on NM_052900.3) | Missense Mutation (SNP) | VAF 82/350 reads (23%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.935); catalogued as COSV52093648, COSV52289780; called by muse, mutect2, varscan2
- CSNK1G3 | c.835A>C p.N279H | Missense Mutation (SNP) | VAF 21/225 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.892); catalogued as COSV100631732; called by muse, mutect2
- CSTF2T | c.284A>C p.E95A | Missense Mutation (SNP) | VAF 34/134 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.392); catalogued as COSV58655935; called by muse, mutect2, varscan2
- CTDSPL2 | c.162A>T p.K54N | Missense Mutation (SNP) | VAF 34/155 reads (22%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.018); catalogued as rs1385582981, COSV52944566; called by muse, mutect2, varscan2
- CTNNBL1 | c.556G>A p.D186N | Missense Mutation (SNP) | VAF 80/334 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.206); catalogued as rs376332701; called by muse, mutect2, varscan2
- CTSL | c.938A>C p.K313T | Missense Mutation (SNP) | VAF 71/315 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.955); catalogued as COSV58245590; called by muse, mutect2, varscan2
- CUX1 | c.106G>A p.E36K (on ENST00000292535 / NM_181552.4; = p.E47K on NM_001913.5) | Missense Mutation (SNP) | VAF 16/166 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.566); catalogued as rs1404930496, COSV52894363; called by muse, mutect2
- CXADR | c.625A>C p.T209P | Missense Mutation (SNP) | VAF 210/687 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV53027675; called by muse, mutect2, varscan2
- CXCL1 | c.152G>A p.G51E | Missense Mutation (SNP) | VAF 57/185 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67611515; called by muse, mutect2, varscan2
- CXCR6 | c.887G>A p.R296Q | Missense Mutation (SNP) | VAF 52/202 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.116); catalogued as rs141955108; called by muse, mutect2, varscan2
- CYBB | c.484-1G>T p.X162_splice | Splice Site (SNP) | VAF 9/104 reads (9%) | catalogued as COSV101059810; called by muse, mutect2
- CYP27C1 | c.981G>T p.E327D | Missense Mutation (SNP) | VAF 7/153 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100080001; called by muse, mutect2
- CYP2C8 | c.1240G>T p.D414Y | Missense Mutation (SNP) | VAF 140/540 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV64875956; called by muse, mutect2
- CYP2U1 | c.1281G>T p.E427D | Missense Mutation (SNP) | VAF 24/138 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.101); catalogued as COSV60548095; called by muse, mutect2, varscan2
- CYP39A1 | c.235G>T p.E79* | Nonsense Mutation (SNP) | VAF 32/342 reads (9%) | catalogued as COSV99242662; called by muse, mutect2
- CYP4F12 | c.882G>T p.K294N | Missense Mutation (SNP) | VAF 57/194 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs758547781, COSV61172173; called by muse, mutect2, varscan2
- CYP7A1 | c.637G>A p.D213N | Missense Mutation (SNP) | VAF 74/310 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749230759, COSV56962076; called by muse, mutect2, varscan2
- CYSLTR1 | c.938C>A p.S313Y | Missense Mutation (SNP) | VAF 59/192 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.564); catalogued as COSV64819295; called by muse, mutect2, varscan2
- CZIB | c.224C>A p.S75Y | Missense Mutation (SNP) | VAF 11/176 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV53758567, COSV99598296; called by muse, mutect2
- DAP3 | c.492T>G p.N164K | Missense Mutation (SNP) | VAF 63/278 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.741); catalogued as COSV58019070; called by muse, mutect2, varscan2
- DAPK1 | c.2834G>A p.R945Q | Missense Mutation (SNP) | VAF 83/348 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.216); catalogued as rs748494486, COSV63783719; called by muse, mutect2, varscan2
- DAPL1 | c.314G>A p.R105Q | Missense Mutation (SNP) | VAF 120/241 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.027); catalogued as rs745794395, COSV59353180; called by muse, mutect2, varscan2
- DBT | c.533G>A p.R178H | Missense Mutation (SNP) | VAF 69/407 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs139251881; called by muse, mutect2, varscan2
- DCAF1 | c.3848G>A p.R1283Q | Missense Mutation (SNP) | VAF 19/192 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV60046385; called by muse, mutect2, varscan2
- DCAF4L2 | c.671G>T p.S224I | Missense Mutation (SNP) | VAF 92/334 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.397); catalogued as COSV60476225, COSV60479508; called by muse, mutect2, varscan2
- DCAF6 | c.1474A>T p.K492* (on ENST00000312263 / NM_001349778.1; = p.K512* on NM_018442.3 and 4 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 60/226 reads (27%) | catalogued as COSV56574521; called by muse, mutect2, varscan2
- DCAF7 | c.134A>G p.N45S | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV59000417; called by muse, mutect2, varscan2
- DCAF8L1 | c.318G>T p.E106D | Missense Mutation (SNP) | VAF 19/287 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.142); catalogued as COSV101491529; called by muse, mutect2
- DCLK1 | c.278G>A p.R93Q | Missense Mutation (SNP) | VAF 52/143 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1366698690, COSV55170182; called by muse, mutect2, varscan2
- DCLRE1A | c.1365A>C p.Q455H | Missense Mutation (SNP) | VAF 105/209 reads (50%) | SIFT tolerated (0.51); PolyPhen benign (0.007); catalogued as COSV63748127; called by muse, mutect2, varscan2
- DCP2 | c.954G>T p.M318I | Missense Mutation (SNP) | VAF 64/287 reads (22%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV66616036; called by muse, mutect2, varscan2
- DCST2 | c.64G>A p.A22T | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT tolerated (0.21); PolyPhen benign (0.025); catalogued as rs1407512243, COSV55049999; called by muse, mutect2, varscan2
- DDB1 | c.3179A>C p.K1060T | Missense Mutation (SNP) | VAF 61/449 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.031); catalogued as COSV57100770; called by muse, mutect2, varscan2
- DDB2 | c.575G>A p.R192Q | Missense Mutation (SNP) | VAF 52/228 reads (23%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as rs763313431, COSV57036907, COSV57039652; called by muse, mutect2, varscan2
- DDHD1 | c.662A>C p.K221T (on ENST00000323669; = p.K418T on NM_030637.3) | Missense Mutation (SNP) | VAF 114/431 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as COSV100080218, COSV60356881; called by muse, mutect2, varscan2
- DDX17 | c.1023A>C p.K341N | Missense Mutation (SNP) | VAF 90/297 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.813); catalogued as COSV53250457; called by muse, mutect2, varscan2
- DDX21 | c.1966G>T p.E656* | Nonsense Mutation (SNP) | VAF 33/566 reads (6%) | catalogued as COSV100826544; called by muse, mutect2
- DDX60 | c.3994G>A p.D1332N | Missense Mutation (SNP) | VAF 28/146 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67094935; called by muse, mutect2, varscan2
- DEFB108B | c.191G>T p.R64I | Missense Mutation (SNP) | VAF 16/113 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV60822235; called by muse, mutect2, varscan2
- DENND4A | c.1869A>C p.Q623H | Missense Mutation (SNP) | VAF 79/256 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV71265152; called by muse, mutect2, varscan2
- DEPDC1 | c.236T>G p.F79C | Missense Mutation (SNP) | VAF 29/338 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100920455; called by muse, mutect2
- DEPDC7 | c.898G>T p.E300* (on ENST00000241051 / NM_001077242.2; = p.E291* on NM_139160.2) | Nonsense Mutation (SNP) | VAF 52/258 reads (20%) | catalogued as COSV53805563; called by mutect2, varscan2
- DGAT2 | c.154G>A p.D52N | Missense Mutation (SNP) | VAF 64/209 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as COSV57175181; called by muse, mutect2, varscan2
- DGCR8 | c.1709G>A p.R570Q | Missense Mutation (SNP) | VAF 62/202 reads (31%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.76); catalogued as rs1173166685, COSV61225545; called by muse, mutect2, varscan2
- DGKH | c.2346A>C p.K782N | Missense Mutation (SNP) | VAF 22/106 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54927193; called by muse, mutect2, varscan2
- DHX15 | c.396G>T p.K132N | Missense Mutation (SNP) | VAF 32/536 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.013); catalogued as COSV100391660; called by muse, mutect2
- DHX29 | c.436A>G p.T146A | Missense Mutation (SNP) | VAF 47/188 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.039); catalogued as COSV52416341; called by muse, mutect2, varscan2
- DHX36 | c.1927A>G p.I643V | Missense Mutation (SNP) | VAF 19/398 reads (5%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.574); catalogued as COSV100273897; called by muse, mutect2
- DICER1 | c.1211G>T p.R404I | Missense Mutation (SNP) | VAF 76/354 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.791); catalogued as COSV58615386; called by muse, mutect2, varscan2
- DIP2B | c.196G>T p.E66* | Nonsense Mutation (SNP) | VAF 80/251 reads (32%) | catalogued as COSV56578291; called by muse, mutect2, varscan2
- DIS3L2 | c.702+1G>A p.X234_splice | Splice Site (SNP) | VAF 31/248 reads (13%) | catalogued as COSV56047540; called by muse, mutect2, varscan2
- DISC1 | c.2033A>C p.K678T | Missense Mutation (SNP) | VAF 159/493 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.952); catalogued as COSV64090827; called by muse, mutect2, varscan2
- DLG1 | c.160G>T p.E54* | Nonsense Mutation (SNP) | VAF 27/179 reads (15%) | catalogued as COSV100015479; called by muse, mutect2, varscan2
- DLG2 | c.2485G>T p.E829* | Nonsense Mutation (SNP) | VAF 105/589 reads (18%) | catalogued as COSV54618835, COSV54636335; called by muse, mutect2, varscan2
- DMD | c.7667G>T p.R2556I | Missense Mutation (SNP) | VAF 84/427 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as COSV58889726, COSV58946219; called by muse, mutect2, varscan2
- DNA2 | c.565G>T p.E189* | Nonsense Mutation (SNP) | VAF 54/255 reads (21%) | catalogued as COSV63063051; called by muse, mutect2, varscan2
- DNAH10 | c.4216G>T p.D1406Y (on ENST00000409039; = p.D1345Y on NM_207437.3) | Missense Mutation (SNP) | VAF 41/134 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV68987439; called by muse, mutect2, varscan2
- DNAH11 | c.11611G>T p.E3871* | Nonsense Mutation (SNP) | VAF 74/265 reads (28%) | catalogued as COSV60937881; called by muse, mutect2, varscan2
- DNAH17 | c.11417C>T p.S3806L | Missense Mutation (SNP) | VAF 35/98 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.289); catalogued as COSV101102065, COSV67749318; called by muse, mutect2, varscan2
- DNAH2 | c.4763C>T p.S1588L | Missense Mutation (SNP) | VAF 88/230 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1484561018, COSV66715954, COSV66720305; called by muse, mutect2, varscan2
- DNAH3 | c.1846T>G p.L616V | Missense Mutation (SNP) | VAF 52/251 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV54501743; called by muse, mutect2, varscan2
- DNAH5 | c.13276G>A p.E4426K | Missense Mutation (SNP) | VAF 67/290 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.311); catalogued as rs777295839, COSV54202122; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAH5 | c.8686A>C p.I2896L | Missense Mutation (SNP) | VAF 78/281 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV54202132; called by muse, mutect2, varscan2
- DNAH5 | c.5530G>T p.E1844* | Nonsense Mutation (SNP) | VAF 56/429 reads (13%) | catalogued as COSV54202142; called by muse, mutect2, varscan2
- DNAH7 | c.11017T>G p.Y3673D | Missense Mutation (SNP) | VAF 85/344 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV56750577; called by muse, mutect2, varscan2
- DNAH7 | c.3767A>C p.K1256T | Missense Mutation (SNP) | VAF 71/249 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.03); catalogued as COSV56750588; called by muse, mutect2, varscan2
- DNAH8 | c.10253G>A p.R3418Q | Missense Mutation (SNP) | VAF 22/520 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.068); catalogued as rs866855066, COSV59436690; called by muse, mutect2
- DNAJC16 | c.1427T>G p.F476C | Missense Mutation (SNP) | VAF 56/240 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.276); catalogued as rs750151843, COSV65448009; called by muse, mutect2, varscan2
- DNAJC27 | c.424C>T p.R142C | Missense Mutation (SNP) | VAF 79/288 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1174599008, COSV53093885; called by muse, mutect2, varscan2
- DNAJC6 | c.2021A>C p.Q674P | Missense Mutation (SNP) | VAF 63/273 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.929); catalogued as COSV54769173; called by muse, mutect2, varscan2
- DNM1L | c.547G>A p.A183T | Missense Mutation (SNP) | VAF 55/247 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs751127554, COSV56771938; called by muse, mutect2, varscan2
- DNM3 | c.1352G>T p.R451I | Missense Mutation (SNP) | VAF 76/271 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.335); catalogued as COSV62452496; called by muse, mutect2, varscan2
- DOCK11 | c.5473G>T p.E1825* | Nonsense Mutation (SNP) | VAF 15/126 reads (12%) | catalogued as COSV52249027, COSV99354548; called by muse, mutect2
- DOCK2 | c.2723T>G p.I908S | Missense Mutation (SNP) | VAF 75/266 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.017); catalogued as COSV56939831; called by muse, mutect2, varscan2
- DOCK8 | c.5138A>G p.D1713G | Missense Mutation (SNP) | VAF 52/187 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.143); catalogued as COSV66617347; called by muse, mutect2, varscan2
- DOCK9 | c.4223C>A p.S1408Y (on ENST00000376460 / NM_001366676.2; = p.S1409Y on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 87/329 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV59618823; called by muse, mutect2, varscan2
- DOCK9 | c.403C>T p.R135* (on ENST00000376460 / NM_001366676.2; = p.R136* on NM_015296.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 65/269 reads (24%) | catalogued as COSV59618853; called by muse, mutect2, varscan2
- DOP1A | c.1806C>A p.F602L | Missense Mutation (SNP) | VAF 40/148 reads (27%) | SIFT tolerated (0.57); PolyPhen benign (0.293); catalogued as COSV52706470; called by muse, mutect2, varscan2
- DRC1 | c.942G>T p.E314D | Missense Mutation (SNP) | VAF 45/194 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV56528631; called by muse, mutect2, varscan2
- DRP2 | c.2395C>T p.L799F | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.601); catalogued as COSV67870543; called by muse, mutect2, varscan2
- DSC3 | c.351G>T p.K117N | Missense Mutation (SNP) | VAF 68/268 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.171); catalogued as COSV64571502; called by muse, mutect2, varscan2
- DSEL | c.449T>C p.V150A | Missense Mutation (SNP) | VAF 49/136 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as rs761954877, COSV59489145; called by muse, mutect2, varscan2
- DSG1 | c.673C>A p.L225I | Missense Mutation (SNP) | VAF 13/106 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV57136149; called by muse, mutect2, varscan2
- DST | c.16523A>C p.E5508A (on ENST00000361203 / NM_001374722.1; = p.E3096A on NM_015548.5) | Missense Mutation (SNP) | VAF 97/401 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV54996032; called by muse, mutect2, varscan2
- DST | c.6343A>C p.I2115L | Missense Mutation (SNP) | VAF 29/165 reads (18%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV54996052; called by muse, mutect2, varscan2
- DST | c.5506G>A p.E1836K | Missense Mutation (SNP) | VAF 37/175 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as rs575951388, COSV54996061; called by muse, mutect2, varscan2
- DST | c.5177G>T p.R1726I | Missense Mutation (SNP) | VAF 93/339 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1453861665, COSV54996069; called by muse, mutect2, varscan2
- DST | c.226C>A p.L76I | Missense Mutation (SNP) | VAF 49/183 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56797529; called by muse, mutect2, varscan2
- DUSP11 | c.938A>C p.K313T | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.012); catalogued as rs1172581102, COSV99731212; called by muse, mutect2
- DUSP26 | c.250C>T p.R84C | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.034); catalogued as rs778191669, COSV56360614; called by muse, mutect2, varscan2
- DYM | c.1916T>G p.F639C | Missense Mutation (SNP) | VAF 49/170 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53979798; called by muse, mutect2, varscan2
- DYNC1LI2 | c.1148C>T p.S383F | Missense Mutation (SNP) | VAF 47/168 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV50754016; called by muse, mutect2, varscan2
- DYNC2H1 | c.6221G>A p.R2074Q | Missense Mutation (SNP) | VAF 127/524 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as rs758993842, COSV62085495; called by muse, mutect2, varscan2
- DYTN | c.1736G>T p.*579Lext*31 | Nonstop Mutation (SNP) | VAF 18/89 reads (20%) | catalogued as COSV71513263; called by muse, varscan2
- E2F8 | c.1016G>A p.R339Q | Missense Mutation (SNP) | VAF 134/540 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs765287674, COSV51461605; called by muse, mutect2, varscan2
- EAPP | c.220A>G p.K74E | Missense Mutation (SNP) | VAF 95/319 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.272); catalogued as COSV51651125; called by muse, mutect2, varscan2
- EBF2 | c.493G>A p.E165K | Missense Mutation (SNP) | VAF 56/426 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.109); catalogued as COSV68775824; called by muse, mutect2, varscan2
- EBF3 | c.1114G>A p.E372K (on ENST00000355311 / NM_001375392.1; = p.E363K on NM_001005463.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/308 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); catalogued as rs1239465330, COSV62479034, COSV62482428; called by muse, mutect2
- ECHDC2 | c.214C>T p.R72W | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as rs368580572; called by muse, varscan2
- EEA1 | c.1454A>C p.K485T | Missense Mutation (SNP) | VAF 212/726 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0.073); catalogued as COSV59282229; called by muse, mutect2, varscan2
- EEF1AKNMT | c.17A>C p.K6T | Missense Mutation (SNP) | VAF 64/231 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.215); catalogued as COSV62282431; called by muse, mutect2, varscan2
- EGF | c.1189+2T>C p.X397_splice | Splice Site (SNP) | VAF 150/537 reads (28%) | catalogued as rs1421670842, COSV54475345; called by muse, mutect2, varscan2
- EGFLAM | c.1214C>A p.S405Y | Missense Mutation (SNP) | VAF 43/754 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100379723; called by muse, mutect2
- EIF2AK3 | c.1093G>T p.D365Y | Missense Mutation (SNP) | VAF 58/366 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.272); catalogued as COSV57544689; called by muse, mutect2, varscan2
- EIF2AK4 | c.1393C>T p.R465C | Missense Mutation (SNP) | VAF 43/339 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as rs752398827, COSV55464600; called by muse, mutect2, varscan2
- EIF2S2 | c.570G>T p.K190N | Missense Mutation (SNP) | VAF 89/376 reads (24%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.991); catalogued as COSV66620870; called by muse, mutect2, varscan2
- EIF2S3 | c.845G>A p.S282N | Missense Mutation (SNP) | VAF 38/916 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV99451104; called by muse, mutect2
- EIF3D | c.59C>T p.A20V | Missense Mutation (SNP) | VAF 40/146 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.23); catalogued as rs150123971; called by muse, mutect2, varscan2
- ELF2 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 92/363 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.022); catalogued as COSV55491369; called by muse, mutect2, varscan2
- ELL | c.167T>G p.F56C | Missense Mutation (SNP) | VAF 38/191 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV53210915; called by muse, mutect2, varscan2
- EML5 | c.5297C>A p.S1766Y (on ENST00000380664; = p.S1774Y on NM_183387.3) | Missense Mutation (SNP) | VAF 136/491 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV100715558, COSV61341356; called by muse, mutect2, varscan2
- EML5 | c.2032C>T p.R678* | Nonsense Mutation (SNP) | VAF 85/514 reads (17%) | catalogued as rs762453622, COSV61341366; called by muse, mutect2, varscan2
- ENAM | c.2962A>C p.N988H | Missense Mutation (SNP) | VAF 39/234 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); catalogued as COSV68535158; called by muse, mutect2, varscan2
- ENDOG | c.802G>A p.E268K | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.646); catalogued as rs776376143, COSV63508744; called by muse, mutect2, varscan2
- ENOPH1 | c.393C>A p.F131L | Missense Mutation (SNP) | VAF 119/624 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV56730295, COSV56731850; called by muse, mutect2, varscan2
- ENOX2 | c.1028C>T p.S343F (on ENST00000338144 / NM_001382520.1; = p.S314F on NM_006375.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/216 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as COSV100584504; called by muse, mutect2
- ENPEP | c.193G>A p.A65T | Missense Mutation (SNP) | VAF 28/145 reads (19%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV54446602; called by muse, mutect2, varscan2
- ENPP5 | c.826G>T p.E276* | Nonsense Mutation (SNP) | VAF 34/174 reads (20%) | catalogued as COSV57907975, COSV57909991; called by muse, mutect2, varscan2
- ENTPD6 | c.680C>T p.S227L | Missense Mutation (SNP) | VAF 58/170 reads (34%) | SIFT tolerated (1); PolyPhen probably damaging (0.975); catalogued as rs777289378, COSV61750847; called by muse, mutect2, varscan2
- ENTPD7 | c.1394C>A p.S465* | Nonsense Mutation (SNP) | VAF 134/519 reads (26%) | catalogued as COSV65111906; called by muse, mutect2, varscan2
- EOGT | c.515+1G>T p.X172_splice | Splice Site (SNP) | VAF 56/251 reads (22%) | catalogued as COSV55149155; called by muse, mutect2, varscan2
- EPB41L1 | c.2480G>A p.R827Q | Missense Mutation (SNP) | VAF 34/123 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs764328855, COSV52433235; called by muse, mutect2, varscan2
- EPHA6 | c.2668C>A p.H890N (on ENST00000389672 / NM_001080448.3; = p.H282N on NM_173655.4) | Missense Mutation (SNP) | VAF 60/259 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV67557542; called by muse, mutect2, varscan2
- EPHB1 | c.980G>A p.R327H | Missense Mutation (SNP) | VAF 28/106 reads (26%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as rs747682274, COSV67653214; called by muse, mutect2, varscan2
- EPS15L1 | c.2185C>T p.P729S | Missense Mutation (SNP) | VAF 33/121 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.424); catalogued as COSV50167130; called by muse, mutect2, varscan2
- ERAP1 | c.2772G>T p.K924N | Missense Mutation (SNP) | VAF 130/500 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.105); catalogued as COSV57085015, COSV57087213; called by muse, mutect2, varscan2
- ERCC3 | c.1934G>A p.R645Q | Missense Mutation (SNP) | VAF 48/193 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1366074068, COSV53425366; called by muse, mutect2, varscan2
- ERCC6L | c.2077G>T p.E693* | Nonsense Mutation (SNP) | VAF 48/185 reads (26%) | catalogued as COSV57819254; called by muse, mutect2, varscan2
- ERI2 | c.446T>G p.F149C | Missense Mutation (SNP) | VAF 26/154 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55499600; called by muse, mutect2, varscan2
- ERICH5 | c.436A>C p.N146H | Missense Mutation (SNP) | VAF 30/138 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.042); catalogued as COSV59314952; called by muse, mutect2, varscan2
- ERICH5 | c.779G>T p.R260I | Missense Mutation (SNP) | VAF 20/110 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV59314961, COSV59315806; called by muse, mutect2, varscan2
- ERLEC1 | c.394C>T p.R132W | Missense Mutation (SNP) | VAF 27/291 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs373922461; called by muse, mutect2
- ERV3-1 | c.973G>A p.E325K | Missense Mutation (SNP) | VAF 100/420 reads (24%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs370257962; called by muse, mutect2, varscan2
- ESCO1 | c.1718G>A p.R573Q | Missense Mutation (SNP) | VAF 95/386 reads (25%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs200657231, COSV52517980; called by muse, mutect2, varscan2
- ESCO2 | c.414A>C p.K138N | Missense Mutation (SNP) | VAF 24/143 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.348); catalogued as rs745340548, COSV59413165; called by muse, mutect2, varscan2
- ESCO2 | c.1241T>G p.F414C | Missense Mutation (SNP) | VAF 50/285 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV59413177; called by muse, mutect2, varscan2
- ESRRG | c.1257G>T p.M419I | Missense Mutation (SNP) | VAF 74/238 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.892); catalogued as COSV63148669; called by muse, mutect2, varscan2
- ETFDH | c.194T>G p.F65C | Missense Mutation (SNP) | VAF 26/312 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.011); catalogued as COSV100310084; called by muse, mutect2
- EYA4 | c.566G>T p.S189I | Missense Mutation (SNP) | VAF 91/374 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.211); catalogued as rs760755612, COSV62045002; called by muse, mutect2, varscan2
- F13B | c.1447G>T p.D483Y | Missense Mutation (SNP) | VAF 89/342 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV66372064; called by muse, mutect2, varscan2
- F2RL1 | c.840G>T p.K280N | Missense Mutation (SNP) | VAF 49/171 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.826); catalogued as COSV56994975, COSV56995608; called by muse, mutect2, varscan2
- FAHD2A | c.913G>T p.E305* | Nonsense Mutation (SNP) | VAF 68/273 reads (25%) | catalogued as COSV51977400; called by muse, mutect2, varscan2
- FAM118A | c.1028C>A p.S343* | Nonsense Mutation (SNP) | VAF 69/301 reads (23%) | catalogued as COSV53418398, COSV99343713; called by muse, mutect2, varscan2
- FAM135A | c.407G>A p.R136Q (on ENST00000370479 / NM_001351599.1; = p.R93Q on NM_020819.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 91/374 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs763924070, COSV52047345; called by muse, mutect2, varscan2
- FAM135A | c.1211C>A p.S404* (on ENST00000370479 / NM_001351599.1; = p.S387* on NM_020819.4 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 80/255 reads (31%) | catalogued as COSV52047368; called by muse, mutect2, varscan2
- FAM155B | c.472G>A p.E158K | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.83); PolyPhen benign (0.169); catalogued as COSV52935145; called by muse, mutect2, varscan2
- FAM169A | c.362G>A p.R121Q | Missense Mutation (SNP) | VAF 43/260 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV65845876; called by muse, mutect2, varscan2
- FAM171B | c.1293A>C p.K431N | Missense Mutation (SNP) | VAF 32/132 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.139); catalogued as COSV59000452; called by muse, mutect2, varscan2
- FAM184A | c.2864T>C p.F955S | Missense Mutation (SNP) | VAF 188/663 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.544); catalogued as COSV58851395; called by muse, mutect2, varscan2
- FAM184A | c.2012T>G p.L671R | Missense Mutation (SNP) | VAF 108/324 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58851405; called by muse, mutect2, varscan2
- FAM200A | c.734G>A p.R245Q | Missense Mutation (SNP) | VAF 71/299 reads (24%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.88); catalogued as rs937143169, COSV68808517; called by muse, mutect2, varscan2
- FAM204A | c.244G>T p.E82* | Nonsense Mutation (SNP) | VAF 51/264 reads (19%) | catalogued as COSV64987523; called by muse, mutect2, varscan2
- FAM227B | c.809C>T p.S270L | Missense Mutation (SNP) | VAF 45/129 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs371405816; called by muse, mutect2, varscan2
- FAM50A | c.762G>T p.E254D | Missense Mutation (SNP) | VAF 22/99 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50130706; called by muse, mutect2, varscan2
- FAM9A | c.310G>T p.E104* | Nonsense Mutation (SNP) | VAF 188/869 reads (22%) | catalogued as COSV101121312, COSV66812892; called by muse, mutect2, varscan2
- FANCB | c.1713G>T p.K571N | Missense Mutation (SNP) | VAF 44/163 reads (27%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.73); catalogued as COSV60758748; called by muse, mutect2, varscan2
- FAP | c.158C>A p.S53Y | Missense Mutation (SNP) | VAF 33/162 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV51858904, COSV51859140; called by muse, mutect2, varscan2
- FARP1 | c.1042C>T p.L348F | Missense Mutation (SNP) | VAF 24/503 reads (5%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.951); catalogued as COSV100131919; called by muse, mutect2
- FAT1 | c.9661C>A p.L3221I | Missense Mutation (SNP) | VAF 14/141 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV71671877, COSV71675550; called by muse, mutect2
- FAT3 | c.1135G>T p.E379* | Nonsense Mutation (SNP) | VAF 84/325 reads (26%) | catalogued as COSV53072200, COSV53124569, COSV99963822; called by muse, mutect2, varscan2
- FAT3 | c.4107C>A p.F1369L | Missense Mutation (SNP) | VAF 131/461 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.45); catalogued as COSV53072230; called by muse, mutect2, varscan2
- FAT3 | c.5602G>T p.E1868* | Nonsense Mutation (SNP) | VAF 87/384 reads (23%) | catalogued as COSV53072252; called by muse, mutect2, varscan2
- FAT3 | c.11136C>A p.F3712L | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.523); catalogued as COSV53072276; called by muse, mutect2, varscan2
- FAT4 | c.3040C>T p.R1014* | Nonsense Mutation (SNP) | VAF 27/116 reads (23%) | catalogued as rs1014593243, COSV67880845, COSV67888914; called by muse, mutect2, varscan2
- FAT4 | c.5749C>T p.R1917* | Nonsense Mutation (SNP) | VAF 11/305 reads (4%) | catalogued as COSV58677867; called by muse, mutect2
- FAT4 | c.7693G>A p.D2565N | Missense Mutation (SNP) | VAF 31/157 reads (20%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.997); catalogued as rs755593093, COSV58670393; called by muse, mutect2, varscan2
- FAT4 | c.9428C>A p.S3143Y | Missense Mutation (SNP) | VAF 18/113 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV58670408; called by muse, mutect2, varscan2
- FBLN1 | c.2080G>A p.V694I | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.979); catalogued as rs761373665, COSV59935842; called by muse, mutect2, varscan2
- FBN1 | c.5128T>G p.L1710V | Missense Mutation (SNP) | VAF 13/327 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100356196; called by muse, mutect2
- FBN2 | c.893C>A p.S298Y | Missense Mutation (SNP) | VAF 74/286 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs577855501, COSV52490642; called by muse, mutect2, varscan2
- FBXO22 | c.979G>A p.V327I | Missense Mutation (SNP) | VAF 142/584 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.404); catalogued as rs748391485, COSV57616480; called by muse, mutect2, varscan2
- FBXO38 | c.802G>T p.E268* | Nonsense Mutation (SNP) | VAF 22/300 reads (7%) | catalogued as COSV57025918, COSV99693861; called by muse, mutect2
- FBXO38 | c.3209G>A p.R1070Q (on ENST00000340253 / NM_205836.3; = p.R995Q on NM_030793.5) | Missense Mutation (SNP) | VAF 27/110 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs761433013, COSV57025550; called by muse, mutect2, varscan2
- FBXW10 | c.2128A>G p.N710D | Missense Mutation (SNP) | VAF 76/211 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.202); catalogued as COSV57314654; called by muse, mutect2, varscan2
- FCAR | c.157C>T p.R53C | Missense Mutation (SNP) | VAF 39/228 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.331); catalogued as rs757200890, COSV62028137, COSV62032319; called by muse, mutect2, varscan2
- FDXACB1 | c.1462T>C p.S488P | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as COSV52786161; called by muse, mutect2, varscan2
- FERMT2 | c.1040A>G p.D347G | Missense Mutation (SNP) | VAF 79/323 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.696); catalogued as COSV58404952; called by muse, mutect2, varscan2
- FERMT2 | c.727C>A p.L243I | Missense Mutation (SNP) | VAF 49/206 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.058); catalogued as COSV58404959; called by muse, mutect2, varscan2
- FGA | c.2569C>T p.R857C | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs754725655, COSV57392507, COSV57394460; called by muse, mutect2, varscan2
- FGB | c.670C>T p.R224C | Missense Mutation (SNP) | VAF 45/157 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as rs772014512, COSV57417348; called by muse, mutect2, varscan2
- FGD4 | c.77G>A p.R26H | Missense Mutation (SNP) | VAF 39/443 reads (9%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.003); catalogued as rs540449675, COSV99847534; called by muse, mutect2
- FGFR1OP2 | c.722C>T p.A241V | Missense Mutation (SNP) | VAF 78/361 reads (22%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.001); catalogued as COSV57586021; called by muse, mutect2, varscan2
- FGL2 | c.283T>C p.S95P | Missense Mutation (SNP) | VAF 68/250 reads (27%) | SIFT tolerated (0.24); PolyPhen benign (0.193); catalogued as COSV50380127; called by muse, mutect2, varscan2
- FIGN | c.1582C>T p.R528W | Missense Mutation (SNP) | VAF 39/185 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs768982332, COSV60762446; called by muse, mutect2, varscan2
- FILIP1 | c.1592A>C p.K531T | Missense Mutation (SNP) | VAF 22/272 reads (8%) | SIFT tolerated (0.28); PolyPhen benign (0.027); catalogued as COSV99385894; called by muse, mutect2
- FKBP6 | c.236A>C p.K79T | Missense Mutation (SNP) | VAF 42/1020 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.274); catalogued as COSV52721440; called by muse, mutect2
- FLI1 | c.785C>T p.P262L | Missense Mutation (SNP) | VAF 49/209 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.509); catalogued as rs772919605, COSV55642274; called by muse, mutect2, varscan2
- FLII | c.2853G>T p.K951N | Missense Mutation (SNP) | VAF 51/322 reads (16%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as COSV57496101; called by muse, mutect2, varscan2
- FLNA | c.7350C>A p.F2450L (on ENST00000369850 / NM_001110556.2; = p.F2442L on NM_001456.3) | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV61036651; called by muse, mutect2, varscan2
- FMR1 | c.963A>C p.E321D | Missense Mutation (SNP) | VAF 223/776 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.029); catalogued as COSV54421221; called by muse, mutect2, varscan2
- FN1 | c.1837G>A p.E613K | Missense Mutation (SNP) | VAF 40/170 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.099); catalogued as rs1272001331, COSV60546022; called by muse, mutect2, varscan2
- FN1 | c.868C>T p.R290C | Missense Mutation (SNP) | VAF 30/107 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.359); catalogued as rs1018955766, COSV60546039; called by muse, mutect2, varscan2
- FNIP1 | c.1583G>A p.R528Q | Missense Mutation (SNP) | VAF 25/99 reads (25%) | SIFT tolerated (0.47); PolyPhen benign (0.18); catalogued as rs371157680; called by muse, mutect2, varscan2
- FOCAD | c.2715A>C p.L905F | Missense Mutation (SNP) | VAF 67/261 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV58093015; called by muse, mutect2, varscan2
- FOCAD | c.2716C>A p.Q906K | Missense Mutation (SNP) | VAF 67/262 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV58093024; called by muse, mutect2, varscan2
- FOXP1 | c.1832A>G p.E611G | Missense Mutation (SNP) | VAF 131/427 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.829); catalogued as COSV59534229; called by muse, mutect2, varscan2
- FOXP1 | c.1673A>G p.N558S | Missense Mutation (SNP) | VAF 62/267 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.118); catalogued as COSV59534237; called by muse, mutect2, varscan2
- FRAS1 | c.10691C>A p.S3564Y | Missense Mutation (SNP) | VAF 8/194 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.133); catalogued as COSV99355275; called by muse, mutect2
- FREM2 | c.1820C>T p.T607M | Missense Mutation (SNP) | VAF 105/426 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as rs115928688, COSV54835903; called by muse, mutect2, varscan2
- FRMPD1 | c.2381A>G p.E794G | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.058); catalogued as COSV66698991; called by muse, mutect2, varscan2
- FSD2 | c.306A>C p.E102D | Missense Mutation (SNP) | VAF 33/103 reads (32%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as COSV58008466; called by muse, mutect2, varscan2
- FSTL5 | c.1592C>T p.S531F | Missense Mutation (SNP) | VAF 36/138 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); catalogued as COSV60179554; called by muse, mutect2, varscan2
- FUT6 | c.771G>T p.E257D | Missense Mutation (SNP) | VAF 30/157 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54604234; called by muse, mutect2, varscan2
- FYB1 | c.1325T>C p.V442A | Missense Mutation (SNP) | VAF 52/224 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV60940457; called by muse, mutect2, varscan2
- FYCO1 | c.2546C>T p.S849L | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as rs766344445, COSV56113288; called by muse, mutect2, varscan2
- FZD6 | c.1247G>A p.R416Q | Missense Mutation (SNP) | VAF 38/252 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs763949530, COSV62470502; called by muse, mutect2, varscan2
- FZD9 | c.1283G>A p.R428H | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs782493264, COSV60669452; called by muse, mutect2, varscan2
- GABBR2 | c.1292T>G p.F431C | Missense Mutation (SNP) | VAF 90/404 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV52292356; called by muse, mutect2, varscan2
- GABRA4 | c.644C>T p.P215L | Missense Mutation (SNP) | VAF 68/256 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51921853; called by muse, mutect2, varscan2
- GABRR1 | c.1245G>T p.E415D | Missense Mutation (SNP) | VAF 18/323 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.015); catalogued as rs1325732475, COSV101034086; called by muse, mutect2
- GALNT11 | c.279A>C p.K93N | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV57424432; called by muse, mutect2, varscan2
- GALNT7 | c.739G>A p.D247N | Missense Mutation (SNP) | VAF 62/235 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778293721, COSV53926558; called by muse, mutect2, varscan2
- GANC | c.1477C>A p.L493I | Missense Mutation (SNP) | VAF 28/584 reads (5%) | PolyPhen possibly damaging (0.703); catalogued as rs1226289464, COSV100530699; called by muse, mutect2
- GAPDHS | c.1130A>C p.D377A | Missense Mutation (SNP) | VAF 38/177 reads (21%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.389); catalogued as COSV55879895; called by muse, mutect2, varscan2
- GAPVD1 | c.242A>C p.Q81P | Missense Mutation (SNP) | VAF 8/249 reads (3%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.888); catalogued as COSV52924045, COSV99783676; called by muse, mutect2
- GAPVD1 | c.3661C>T p.R1221* (on ENST00000394104; = p.R1230* on NM_015635.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 38/149 reads (26%) | catalogued as COSV52919740; called by muse, mutect2, varscan2
- GBA3 | c.867C>A p.F289L | Missense Mutation (SNP) | VAF 16/180 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.514); catalogued as COSV101545557, COSV72438460; called by muse, mutect2
- GCG | c.217G>T p.D73Y | Missense Mutation (SNP) | VAF 64/299 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV64960757; called by muse, mutect2, varscan2
- GCNA | c.309C>T p.D103= | Splice Region (SNP) | VAF 111/404 reads (27%) | catalogued as rs764174655, COSV65465738; called by muse, mutect2, varscan2
- GET1-SH3BGR | c.355G>T p.E119* | Nonsense Mutation (SNP) | VAF 97/369 reads (26%) | catalogued as COSV61321585; called by muse, mutect2, varscan2
- GFOD1 | c.655G>T p.D219Y | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64954221; called by muse, mutect2, varscan2
- GIGYF2 | c.413G>T p.R138I | Missense Mutation (SNP) | VAF 41/987 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.58); catalogued as COSV65248118; called by muse, mutect2
- GIGYF2 | c.1039G>T p.E347* | Nonsense Mutation (SNP) | VAF 45/158 reads (28%) | catalogued as COSV65246015; called by muse, mutect2, varscan2
- GIN1 | c.181C>T p.R61C | Missense Mutation (SNP) | VAF 55/195 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.019); catalogued as rs782667095, COSV67535928; called by muse, mutect2, varscan2
- GIPC2 | c.343G>A p.E115K | Missense Mutation (SNP) | VAF 86/313 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs758543783, COSV66127995; called by muse, mutect2, varscan2
- GJA1 | c.157C>T p.R53C | Missense Mutation (SNP) | VAF 71/230 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as rs1189422011, COSV56996867, COSV56997288; called by muse, mutect2, varscan2
- GJA9 | c.1466A>C p.N489T | Missense Mutation (SNP) | VAF 51/175 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.027); catalogued as COSV62531704; called by muse, mutect2, varscan2
- GK | c.549T>G p.I183M | Missense Mutation (SNP) | VAF 47/236 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.914); catalogued as COSV66735210; called by muse, mutect2, varscan2
- GLB1L2 | c.376G>A p.E126K | Missense Mutation (SNP) | VAF 41/272 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.097); catalogued as COSV60277103; called by muse, mutect2, varscan2
- GNAQ | c.340C>T p.R114* | Nonsense Mutation (SNP) | VAF 74/313 reads (24%) | catalogued as COSV54106266, COSV99680920; called by muse, mutect2, varscan2
- GNPTAB | c.3566G>A p.R1189Q | Missense Mutation (SNP) | VAF 94/344 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.704); catalogued as rs141007019; called by muse, mutect2, varscan2
- GNPTAB | c.1384G>A p.D462N | Missense Mutation (SNP) | VAF 49/244 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs1342010486, COSV54776348; called by muse, mutect2, varscan2
- GOLGA4 | c.2263A>C p.K755Q | Missense Mutation (SNP) | VAF 21/117 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.558); catalogued as COSV62709005; called by muse, mutect2, varscan2
- GOLGA5 | c.191C>A p.S64* | Nonsense Mutation (SNP) | VAF 60/271 reads (22%) | catalogued as COSV50831951, COSV99370938; called by muse, mutect2, varscan2
- GOLGA5 | c.1483G>A p.E495K | Missense Mutation (SNP) | VAF 42/151 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as rs574595272, COSV50831955; called by muse, mutect2, varscan2
- GOLGA8A | c.1824G>T p.E608D (on ENST00000432566; = p.E580D on NM_181077.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 34/169 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV62169017; called by muse, mutect2, varscan2
- GON4L | c.1490C>A p.S497Y | Missense Mutation (SNP) | VAF 65/278 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV55185634; called by muse, mutect2, varscan2
- GORASP2 | c.460G>A p.E154K | Missense Mutation (SNP) | VAF 57/236 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.577); catalogued as rs779935932, COSV52200706, COSV52202881; called by muse, mutect2, varscan2
- GPAM | c.2458G>T p.E820* | Nonsense Mutation (SNP) | VAF 12/314 reads (4%) | catalogued as COSV100788389; called by muse, mutect2
- GPATCH8 | c.3413C>A p.S1138Y | Missense Mutation (SNP) | VAF 34/83 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.687); catalogued as COSV59193021; called by muse, mutect2, varscan2
- GPC3 | c.1093G>T p.D365Y | Missense Mutation (SNP) | VAF 61/248 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV63658177; called by muse, mutect2, varscan2
- GPC5 | c.901G>T p.E301* | Nonsense Mutation (SNP) | VAF 20/128 reads (16%) | catalogued as COSV65573598; called by muse, mutect2, varscan2
- GPKOW | c.1357G>T p.E453* | Nonsense Mutation (SNP) | VAF 89/379 reads (23%) | catalogued as COSV50242059; called by muse, mutect2, varscan2
- GPKOW | c.434A>C p.D145A | Missense Mutation (SNP) | VAF 25/96 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.192); catalogued as COSV50242066; called by muse, mutect2, varscan2
- GPN3 | c.51C>T p.S17= | Splice Region (SNP) | VAF 77/241 reads (32%) | catalogued as rs577425537, COSV57400979; called by muse, mutect2, varscan2
- GPR107 | c.854G>A p.R285Q | Missense Mutation (SNP) | VAF 117/379 reads (31%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.732); catalogued as rs200754726, COSV61277037; called by muse, mutect2, varscan2
- GPR135 | c.1291C>T p.R431* | Nonsense Mutation (SNP) | VAF 13/51 reads (25%) | catalogued as rs546298096, COSV67749423; called by muse, mutect2, varscan2
- GPR141 | c.882G>T p.K294N | Missense Mutation (SNP) | VAF 81/319 reads (25%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.071); catalogued as COSV57731196, COSV57733250; called by muse, mutect2, varscan2
- GPR158 | c.444G>T p.Q148H | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT tolerated (0.28); PolyPhen benign (0.015); catalogued as COSV66264626; called by muse, mutect2, varscan2
- GPR158 | c.2026G>A p.D676N | Missense Mutation (SNP) | VAF 63/285 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV66264635; called by muse, mutect2, varscan2
- GPR52 | c.986G>A p.R329Q | Missense Mutation (SNP) | VAF 32/106 reads (30%) | SIFT tolerated (0.28); PolyPhen benign (0.021); catalogued as rs773501217, COSV52274704; called by muse, mutect2, varscan2
- GPR85 | c.634C>T p.R212* | Nonsense Mutation (SNP) | VAF 28/96 reads (29%) | catalogued as COSV51782558; called by muse, mutect2, varscan2
- GPRASP2 | c.1903C>T p.R635* | Nonsense Mutation (SNP) | VAF 129/426 reads (30%) | catalogued as COSV59990181; called by muse, mutect2, varscan2
- GPX5 | c.525G>T p.K175N | Missense Mutation (SNP) | VAF 54/202 reads (27%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.861); catalogued as COSV69079048; called by muse, mutect2, varscan2
- GRAMD1C | c.527T>C p.V176A | Missense Mutation (SNP) | VAF 133/678 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV63981669; called by muse, varscan2
- GRB10 | c.1612A>T p.K538* (on ENST00000398812; = p.K492* on NM_001001549.3) | Nonsense Mutation (SNP) | VAF 90/303 reads (30%) | catalogued as COSV60007098; called by muse, mutect2, varscan2
- GRB10 | c.1134G>T p.L378F (on ENST00000398812; = p.L332F on NM_001001549.3) | Missense Mutation (SNP) | VAF 98/376 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.092); catalogued as COSV60007108; called by muse, mutect2, varscan2
- GRHL3 | c.345G>T p.E115D (on ENST00000350501 / NM_198174.3; = p.E120D on NM_021180.3) | Missense Mutation (SNP) | VAF 20/122 reads (16%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as COSV52563958; called by muse, mutect2, varscan2
- GRIA3 | c.664G>A p.E222K | Missense Mutation (SNP) | VAF 77/298 reads (26%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.973); catalogued as rs778052374, COSV52047915; called by muse, mutect2, varscan2
- GRIA4 | c.743C>A p.S248Y | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.353); catalogued as COSV56880180; called by muse, mutect2, varscan2
- GRID2 | c.74C>T p.S25L | Missense Mutation (SNP) | VAF 108/404 reads (27%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.706); catalogued as COSV56169290; called by muse, mutect2, varscan2
- GRM3 | c.1549G>T p.E517* | Nonsense Mutation (SNP) | VAF 32/127 reads (25%) | catalogued as COSV64466465, COSV64466671; called by muse, mutect2, varscan2
- GSPT1 | c.911T>C p.L304P (on ENST00000420576 / NM_001130007.2; = p.L442P on NM_002094.4) | Missense Mutation (SNP) | VAF 88/350 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV70452392; called by muse, mutect2, varscan2
- GTF3C3 | c.1207G>T p.E403* | Nonsense Mutation (SNP) | VAF 78/322 reads (24%) | catalogued as COSV55830783; called by muse, mutect2, varscan2
- GUCY1A1 | c.1341G>T p.K447N | Missense Mutation (SNP) | VAF 49/213 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56648773; called by muse, mutect2, varscan2
- GUCY1A2 | c.2135C>T p.S712L | Missense Mutation (SNP) | VAF 18/434 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.574); catalogued as rs1383258563, COSV56477773; called by muse, mutect2
- GUCY2C | c.2204G>T p.R735I | Missense Mutation (SNP) | VAF 132/553 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as COSV53786419, COSV53793609; called by muse, mutect2, varscan2
- GUCY2F | c.3094C>T p.L1032F | Missense Mutation (SNP) | VAF 101/362 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765026247, COSV54298003, COSV54300262; called by muse, mutect2, varscan2
- GUCY2F | c.1477C>T p.R493C | Missense Mutation (SNP) | VAF 137/443 reads (31%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.762); catalogued as COSV54298014; called by muse, mutect2, varscan2
- GYS2 | c.2082G>T p.K694N | Missense Mutation (SNP) | VAF 92/387 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as COSV53920233; called by muse, mutect2, varscan2
- H3C3 | c.32C>G p.S11C | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.56); catalogued as COSV63550632, COSV63551056; called by muse, mutect2, varscan2
- HABP2 | c.693T>G p.F231L | Missense Mutation (SNP) | VAF 16/358 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.422); catalogued as COSV100668079; called by muse, mutect2
- HAUS6 | c.2443G>T p.D815Y | Missense Mutation (SNP) | VAF 42/187 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.515); catalogued as COSV65839462; called by muse, mutect2, varscan2
- HAVCR1 | c.433C>T p.R145* | Nonsense Mutation (SNP) | VAF 183/630 reads (29%) | catalogued as COSV59397432, COSV59401595; called by muse, mutect2, varscan2
- HDAC3 | c.295G>A p.G99R | Missense Mutation (SNP) | VAF 39/133 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778696535, COSV59494972; called by muse, mutect2, varscan2
- HDLBP | c.2872G>T p.E958* | Nonsense Mutation (SNP) | VAF 67/254 reads (26%) | catalogued as COSV60491706; called by muse, mutect2, varscan2
- HDLBP | c.494T>C p.V165A | Missense Mutation (SNP) | VAF 165/627 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); catalogued as COSV60491718; called by muse, mutect2, varscan2
- HECA | c.1051G>A p.E351K | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as rs747226950, COSV62768381; called by muse, mutect2, varscan2
- HEPACAM | c.893G>A p.R298Q | Missense Mutation (SNP) | VAF 46/172 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.148); catalogued as rs1464489453, COSV53428441; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HEPH | c.3309G>T p.K1103N (on ENST00000343002; = p.K836N on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 37/734 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.056); catalogued as COSV100295550, COSV57959020; called by muse, mutect2
- HES1 | c.13A>C p.I5L | Missense Mutation (SNP) | VAF 17/31 reads (55%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); catalogued as COSV51683680; called by muse, mutect2, varscan2
- HFM1 | c.2806A>C p.K936Q | Missense Mutation (SNP) | VAF 18/288 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.718); catalogued as COSV99646646; called by muse, mutect2
- HHAT | c.775G>A p.E259K | Missense Mutation (SNP) | VAF 37/118 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770748303, COSV54790756; called by muse, mutect2, varscan2
- HHATL | c.217C>T p.R73C | Missense Mutation (SNP) | VAF 36/118 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs202051255, COSV60040769; called by muse, mutect2, varscan2
- HHIPL1 | c.1524G>T p.E508D | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58088931; called by muse, mutect2, varscan2
- HIGD1A | c.254G>A p.R85Q | Missense Mutation (SNP) | VAF 63/252 reads (25%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs565556493, COSV58414573, COSV58414971; called by muse, mutect2, varscan2
- HIVEP1 | c.64G>T p.E22* | Nonsense Mutation (SNP) | VAF 10/180 reads (6%) | catalogued as COSV65100291, COSV65100691; called by muse, mutect2
- HLTF | c.1017G>T p.M339I | Missense Mutation (SNP) | VAF 208/860 reads (24%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV59498603; called by muse, mutect2, varscan2
- HMMR | c.1129G>T p.E377* | Nonsense Mutation (SNP) | VAF 74/283 reads (26%) | catalogued as COSV62373640; called by muse, mutect2, varscan2
- HNRNPA3 | c.668T>G p.F223C | Missense Mutation (SNP) | VAF 148/612 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.839); catalogued as COSV66820618; called by muse, mutect2, varscan2
- HOGA1 | c.867G>T p.K289N | Missense Mutation (SNP) | VAF 34/161 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56729130; called by muse, mutect2, varscan2
- HOXC8 | c.560G>A p.G187E | Missense Mutation (SNP) | VAF 24/446 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.343); catalogued as COSV50000373; called by muse, mutect2
- HOXD8 | c.782T>G p.F261C | Missense Mutation (SNP) | VAF 19/198 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV57484905; called by muse, mutect2
- HPS1 | c.1700C>T p.S567L | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs375906039; called by muse, mutect2, varscan2
- HPS4 | c.1915G>A p.E639K | Missense Mutation (SNP) | VAF 17/91 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.24); catalogued as rs1305089281, COSV61102442; called by muse, mutect2, varscan2
- HS3ST1 | c.578G>A p.R193H | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); catalogued as COSV50022987; called by muse, mutect2, varscan2
- HSPA4 | c.160A>C p.S54R | Missense Mutation (SNP) | VAF 104/706 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.567); catalogued as COSV59181552; called by muse, mutect2, varscan2
- HSPD1 | c.541G>T p.E181* | Nonsense Mutation (SNP) | VAF 107/356 reads (30%) | catalogued as COSV61443427, COSV61446053; called by muse, mutect2, varscan2
- HTR1A | c.1228G>A p.A410T | Missense Mutation (SNP) | VAF 39/143 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60499703; called by muse, mutect2, varscan2
- HTR1B | c.577G>A p.E193K | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT tolerated (0.71); PolyPhen benign (0.129); catalogued as rs780026953, COSV64051042; called by muse, mutect2, varscan2
- HTT | c.1330C>T p.L444F | Missense Mutation (SNP) | VAF 43/213 reads (20%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.014); catalogued as rs779703721, COSV61857030; called by muse, mutect2, varscan2
- HUWE1 | c.2354C>T p.T785I | Missense Mutation (SNP) | VAF 90/343 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.316); catalogued as COSV53333545; called by muse, mutect2, varscan2
- ICAM3 | c.1233G>T p.L411F | Missense Mutation (SNP) | VAF 45/238 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.056); catalogued as COSV50328255; called by muse, mutect2, varscan2
- ICE1 | c.3731C>T p.S1244L | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs370101868; called by muse, mutect2, varscan2
- IDO1 | c.1193C>T p.S398F | Missense Mutation (SNP) | VAF 30/130 reads (23%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV53712790, COSV99037414; called by muse, mutect2, varscan2
- IDO2 | c.850C>T p.R284C (on ENST00000389060; = p.R297C on NM_194294.2) | Missense Mutation (SNP) | VAF 40/229 reads (17%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs765222349, COSV58423342; called by muse, mutect2, varscan2
- IFIH1 | c.1061C>T p.S354F | Missense Mutation (SNP) | VAF 72/284 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.832); catalogued as rs751669754, COSV55124394; called by muse, mutect2, varscan2
- IFT88 | c.1562G>T p.R521I (on ENST00000319980 / NM_001318493.2; = p.R512I on NM_006531.5 and 9 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 41/147 reads (28%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.972); catalogued as COSV60671043; called by muse, mutect2, varscan2
- IGDCC3 | c.445G>A p.V149M | Missense Mutation (SNP) | VAF 56/206 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.052); catalogued as rs577502873, COSV60076312; called by muse, mutect2, varscan2
- IGF2BP2 | c.1237C>A p.H413N | Missense Mutation (SNP) | VAF 111/426 reads (26%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as COSV60482565, COSV60484841; called by muse, mutect2, varscan2
- IGF2R | c.6454G>T p.D2152Y | Missense Mutation (SNP) | VAF 17/149 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.771); catalogued as COSV63482125; called by muse, mutect2, varscan2
- IGFBP1 | c.530G>A p.R177Q | Missense Mutation (SNP) | VAF 54/203 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.03); catalogued as rs369196046; called by muse, mutect2, varscan2
- IGFN1 | c.2899C>T p.R967C (on ENST00000295591 / NM_001367841.1; = p.R3424C on NM_001164586.2) | Missense Mutation (SNP) | VAF 48/171 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs781677901, COSV55165331; called by muse, mutect2, varscan2
- IGHMBP2 | c.2828G>T p.R943I | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.556); catalogued as rs779871930, COSV54819863, COSV54820280, COSV54825435; called by muse, mutect2, varscan2
- IGLV3-27 | c.98C>T p.P33L | Missense Mutation (SNP) | VAF 32/102 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs370031900; called by muse, mutect2, varscan2
- IL13 | c.421C>T p.R141C | Missense Mutation (SNP) | VAF 76/268 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.044); catalogued as rs201475069, COSV58733981; called by muse, mutect2, varscan2
- IL21 | c.97G>T p.D33Y | Missense Mutation (SNP) | VAF 91/401 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV52645339; called by muse, mutect2, varscan2
- IL23R | c.1636C>A p.L546I | Missense Mutation (SNP) | VAF 11/114 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100724898; called by muse, mutect2, varscan2
- ILKAP | c.179-1G>A p.X60_splice | Splice Site (SNP) | VAF 115/442 reads (26%) | catalogued as COSV54517219; called by muse, mutect2, varscan2
- IPO9 | c.2548T>G p.F850V | Missense Mutation (SNP) | VAF 43/155 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV64232720; called by muse, mutect2, varscan2
- IQCF2 | c.10C>T p.R4* | Nonsense Mutation (SNP) | VAF 79/258 reads (31%) | catalogued as rs201262177, COSV60761034; called by muse, mutect2, varscan2
- IQUB | c.1077G>T p.E359D | Missense Mutation (SNP) | VAF 31/615 reads (5%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV61239060; called by muse, mutect2
- IRAK3 | c.1207C>A p.L403I | Missense Mutation (SNP) | VAF 45/159 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.558); catalogued as COSV54159111; called by muse, mutect2, varscan2
- IRAK3 | c.1588G>A p.E530K | Missense Mutation (SNP) | VAF 13/318 reads (4%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.011); catalogued as COSV99706399; called by muse, mutect2
- IRF8 | c.325G>A p.V109I | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.901); catalogued as rs1177789656, COSV51896472; called by muse, mutect2, varscan2
- ITGAM | c.832G>T p.E278* | Nonsense Mutation (SNP) | VAF 55/169 reads (33%) | catalogued as COSV54933547; called by muse, mutect2, varscan2
- ITGAX | c.2794G>A p.E932K | Missense Mutation (SNP) | VAF 40/153 reads (26%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.822); catalogued as rs867400184, COSV51641108; called by muse, mutect2, varscan2
- ITIH5 | c.882G>T p.K294N | Missense Mutation (SNP) | VAF 55/433 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV53659358; called by muse, mutect2, varscan2
- ITIH6 | c.3494C>A p.S1165Y | Missense Mutation (SNP) | VAF 68/290 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV54486143, COSV54492656; called by muse, mutect2, varscan2
- ITIH6 | c.2986G>A p.A996T | Missense Mutation (SNP) | VAF 71/242 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as rs1370135414, COSV54486154; called by muse, mutect2, varscan2
- ITIH6 | c.846G>T p.K282N | Missense Mutation (SNP) | VAF 56/200 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as COSV54486166; called by muse, mutect2, varscan2
- ITIH6 | c.770T>G p.I257S | Missense Mutation (SNP) | VAF 70/272 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as COSV54486176; called by muse, mutect2, varscan2
- ITM2A | c.685C>T p.R229C | Missense Mutation (SNP) | VAF 47/181 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs757729384, COSV100964472, COSV64810539; called by muse, mutect2, varscan2
- ITPR1 | c.1021C>T p.R341* (on ENST00000354582; = p.R326* on NM_002222.7) | Nonsense Mutation (SNP) | VAF 81/289 reads (28%) | catalogued as COSV56966806; called by muse, mutect2, varscan2
- ITPR1 | c.5084C>T p.S1695F (on ENST00000354582; = p.S1689F on NM_001168272.2) | Missense Mutation (SNP) | VAF 177/708 reads (25%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.084); catalogued as COSV56966851; called by muse, mutect2, varscan2
- ITPR1 | c.7534G>T p.E2512* (on ENST00000354582; = p.E2457* on NM_002222.7) | Nonsense Mutation (SNP) | VAF 57/227 reads (25%) | catalogued as COSV100230429, COSV56966867; called by muse, mutect2, varscan2
- ITPRIPL1 | c.11-6C>A | Splice Region (SNP) | VAF 38/141 reads (27%) | catalogued as COSV63152552; called by muse, mutect2, varscan2
- JADE3 | c.1234C>T p.R412* | Nonsense Mutation (SNP) | VAF 27/119 reads (23%) | catalogued as COSV54464030; called by muse, mutect2, varscan2
- JMY | c.1132G>A p.E378K | Missense Mutation (SNP) | VAF 70/247 reads (28%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.926); catalogued as rs1160010461, COSV68659219; called by muse, mutect2
- KANK4 | c.1153C>T p.R385* | Nonsense Mutation (SNP) | VAF 16/274 reads (6%) | catalogued as rs1311359487, COSV62985750; called by muse, mutect2
- KANK4 | c.48G>T p.E16D | Missense Mutation (SNP) | VAF 31/153 reads (20%) | SIFT tolerated (0.43); PolyPhen benign (0.02); catalogued as COSV62985254; called by muse, mutect2, varscan2
- KAT6B | c.802G>A p.E268K | Missense Mutation (SNP) | VAF 16/167 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs1427379278, COSV54755819, COSV99768879; called by muse, mutect2
- KBTBD3 | c.1066C>T p.R356* | Nonsense Mutation (SNP) | VAF 72/248 reads (29%) | catalogued as rs1330796361, COSV73241195; called by muse, mutect2, varscan2
- KBTBD7 | c.469C>T p.R157W | Missense Mutation (SNP) | VAF 38/144 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65266025; called by muse, mutect2, varscan2
- KBTBD8 | c.275G>T p.R92L | Missense Mutation (SNP) | VAF 79/320 reads (25%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.859); catalogued as COSV55126318, COSV55127130; called by muse, mutect2, varscan2
- KCND3 | c.1313C>T p.S438L | Missense Mutation (SNP) | VAF 22/125 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0.066); catalogued as rs1172444288, COSV56174369; called by muse, mutect2, varscan2
- KCNH5 | c.2499A>C p.K833N | Missense Mutation (SNP) | VAF 103/458 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.111); catalogued as COSV59751247; called by muse, mutect2, varscan2
- KCNQ5 | c.542C>T p.S181F | Missense Mutation (SNP) | VAF 179/875 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59648044, COSV59671953; called by muse, mutect2, varscan2
- KCNS2 | c.631G>A p.D211N | Missense Mutation (SNP) | VAF 39/138 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.151); catalogued as rs138992941; called by muse, mutect2, varscan2
- KCTD19 | c.399G>A p.W133* | Nonsense Mutation (SNP) | VAF 79/325 reads (24%) | catalogued as COSV58570944, COSV58573144; called by muse, mutect2, varscan2
- KDM3B | c.2948A>C p.D983A | Missense Mutation (SNP) | VAF 8/198 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100070170; called by muse, mutect2
- KDM3B | c.3073C>T p.R1025C | Missense Mutation (SNP) | VAF 80/294 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as rs763983126, COSV58687503; called by muse, mutect2, varscan2
- KDM5A | c.2678G>A p.R893Q | Missense Mutation (SNP) | VAF 70/269 reads (26%) | SIFT tolerated (0.51); PolyPhen benign (0.019); catalogued as rs774366438, COSV66990171; called by muse, mutect2, varscan2
- KERA | c.301A>C p.N101H | Missense Mutation (SNP) | VAF 34/836 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV57131277; called by muse, mutect2
- KIAA0586 | c.2801C>A p.S934* (on ENST00000619416 / NM_001244190.2; = p.S873* on NM_014749.5) | Nonsense Mutation (SNP) | VAF 13/380 reads (3%) | catalogued as COSV99708730; called by muse, mutect2
- KIAA0753 | c.329G>A p.R110Q | Missense Mutation (SNP) | VAF 73/198 reads (37%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs1174601461, COSV100810587, COSV63816669; called by muse, mutect2, varscan2
- KIAA1109 | c.14230C>T p.R4744C | Missense Mutation (SNP) | VAF 53/227 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.027); catalogued as rs1239766017, COSV52661581; called by muse, mutect2, varscan2
- KIAA1755 | c.1146C>A p.D382E | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.89); PolyPhen benign (0.039); catalogued as COSV54073390; called by muse, mutect2, varscan2
- KIAA2026 | c.1720C>T p.R574C | Missense Mutation (SNP) | VAF 27/243 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs1169354787, COSV67353141; called by muse, mutect2, varscan2
- KIAA2026 | c.868C>A p.L290I | Missense Mutation (SNP) | VAF 128/460 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV67353145; called by muse, mutect2, varscan2
- KIF11 | c.2709A>C p.K903N | Missense Mutation (SNP) | VAF 54/186 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0.24); catalogued as COSV53268524; called by muse, mutect2, varscan2
- KIF14 | c.2149A>G p.R717G | Missense Mutation (SNP) | VAF 96/316 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as COSV66259707; called by muse, mutect2, varscan2
- KIF1B | c.3875G>A p.R1292Q (on ENST00000377086 / NM_001365952.1; = p.R1246Q on NM_015074.3) | Missense Mutation (SNP) | VAF 12/254 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55812389; called by muse, mutect2
- KIF20B | c.160G>A p.E54K | Missense Mutation (SNP) | VAF 34/105 reads (32%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.641); catalogued as rs1323971498, COSV53301930; called by muse, mutect2, varscan2
- KIF20B | c.5148A>G p.I1716M (on ENST00000371728 / NM_001284259.2; = p.I1676M on NM_016195.4) | Missense Mutation (SNP) | VAF 88/332 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.135); catalogued as COSV53301941; called by muse, mutect2, varscan2
- KIF21A | c.401A>C p.K134T | Missense Mutation (SNP) | VAF 61/218 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.049); catalogued as COSV62766689; called by muse, mutect2, varscan2
- KIFBP | c.1323G>T p.E441D | Missense Mutation (SNP) | VAF 59/224 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.306); catalogued as COSV62831222; called by muse, mutect2, varscan2
- KLHDC4 | c.69G>T p.K23N | Missense Mutation (SNP) | VAF 38/167 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.544); catalogued as COSV54505836; called by muse, mutect2, varscan2
- KLHL11 | c.1334C>A p.S445Y | Missense Mutation (SNP) | VAF 36/118 reads (31%) | SIFT tolerated (0.82); PolyPhen benign (0.025); catalogued as COSV59861338; called by muse, mutect2, varscan2
- KLHL13 | c.1039G>T p.G347* | Nonsense Mutation (SNP) | VAF 65/243 reads (27%) | catalogued as COSV53244313; called by muse, mutect2, varscan2
- KLHL14 | c.1512G>T p.M504I | Missense Mutation (SNP) | VAF 126/475 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.785); catalogued as COSV63830383; called by muse, mutect2, varscan2
- KLHL23 | c.479G>T p.R160I | Missense Mutation (SNP) | VAF 34/118 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.593); catalogued as COSV55865561; called by muse, mutect2, varscan2
- KLHL28 | c.85C>T p.R29C | Missense Mutation (SNP) | VAF 41/150 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1228514322, COSV61887304; called by muse, mutect2, varscan2
- KLHL4 | c.339G>T p.K113N | Missense Mutation (SNP) | VAF 28/104 reads (27%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.017); catalogued as rs186431341, COSV64138698; called by muse, mutect2, varscan2
- KLHL40 | c.1797G>T p.E599D | Missense Mutation (SNP) | VAF 8/131 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.939); catalogued as COSV99040120, COSV99825726; called by muse, mutect2
- KLHL7 | c.1091C>T p.S364L (on ENST00000339077 / NM_001031710.3; = p.S316L on NM_018846.5) | Missense Mutation (SNP) | VAF 65/238 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.476); catalogued as COSV59159554; called by muse, mutect2, varscan2
- KMO | c.538A>C p.K180Q | Missense Mutation (SNP) | VAF 112/384 reads (29%) | SIFT tolerated (0.67); PolyPhen benign (0.047); catalogued as COSV63807415; called by muse, mutect2, varscan2
- KMT2E | c.2621G>A p.R874Q | Missense Mutation (SNP) | VAF 63/229 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); catalogued as COSV57569165; called by muse, mutect2, varscan2
- KMT5B | c.24G>T p.K8N | Missense Mutation (SNP) | VAF 132/569 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1425527898, COSV58563466, COSV58563958; called by muse, mutect2, varscan2
- KNL1 | c.1457C>A p.A486D (on ENST00000346991 / NM_170589.5; = p.A460D on NM_144508.5) | Missense Mutation (SNP) | VAF 28/89 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.014); catalogued as COSV61150768; called by muse, mutect2, varscan2
- KNTC1 | c.2693G>T p.R898I | Missense Mutation (SNP) | VAF 22/704 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.278); catalogued as COSV100338713; called by muse, mutect2
- KPNA1 | c.140G>A p.R47Q | Missense Mutation (SNP) | VAF 105/426 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1434807039, COSV60267564; called by muse, mutect2, varscan2
- KRT20 | c.569T>C p.L190S | Missense Mutation (SNP) | VAF 127/345 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV51423852; called by muse, mutect2, varscan2
- KRT75 | c.1082G>A p.R361Q | Missense Mutation (SNP) | VAF 115/418 reads (28%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.642); catalogued as rs754329186, COSV52870843; called by muse, mutect2, varscan2
- L1CAM | c.2809C>T p.R937C | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.75); catalogued as rs141213959, COSV62826656; called by muse, mutect2, varscan2
- L1TD1 | c.1881G>T p.E627D | Missense Mutation (SNP) | VAF 27/121 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.187); catalogued as COSV63133038; called by muse, varscan2
- L1TD1 | c.1981G>T p.E661* | Nonsense Mutation (SNP) | VAF 26/120 reads (22%) | catalogued as COSV63133041; called by muse, varscan2
- L1TD1 | c.2080G>A p.E694K | Missense Mutation (SNP) | VAF 41/147 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as rs546879656, COSV63133044; called by muse, mutect2, varscan2
- LAMA1 | c.7237G>T p.E2413* | Nonsense Mutation (SNP) | VAF 81/327 reads (25%) | catalogued as COSV67531466; called by muse, mutect2, varscan2
- LAMA2 | c.178G>T p.E60* | Nonsense Mutation (SNP) | VAF 172/565 reads (30%) | catalogued as COSV70337375, COSV70343666; called by muse, mutect2, varscan2
- LAMA2 | c.1071A>C p.E357D | Missense Mutation (SNP) | VAF 84/300 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.011); catalogued as COSV69000500; called by muse, mutect2, varscan2
- LAMA3 | c.8074C>T p.R2692C (on ENST00000313654 / NM_198129.4; = p.R1083C on NM_000227.6) | Missense Mutation (SNP) | VAF 74/325 reads (23%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.466); catalogued as rs768962336, COSV52529237; called by muse, mutect2, varscan2
- LAMB1 | c.2244A>T p.K748N | Missense Mutation (SNP) | VAF 18/194 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.758); catalogued as COSV99741545; called by muse, mutect2
- LAS1L | c.748G>A p.E250K | Missense Mutation (SNP) | VAF 112/448 reads (25%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs367824164, COSV56706234, COSV56706246; called by muse, mutect2, varscan2
- LCAT | c.845C>T p.A282V | Missense Mutation (SNP) | VAF 43/165 reads (26%) | SIFT tolerated (0.67); PolyPhen benign (0.003); catalogued as rs1221945564, COSV50452035; called by muse, mutect2, varscan2
- LCK | c.542A>C p.Y181S | Missense Mutation (SNP) | VAF 48/197 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60738488; called by muse, mutect2, varscan2
- LDB3 | c.734T>C p.V245A | Missense Mutation (SNP) | VAF 39/141 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV53937465; called by muse, mutect2, varscan2
- LDLRAD4 | c.499G>T p.D167Y | Missense Mutation (SNP) | VAF 25/126 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV63333482; called by muse, mutect2, varscan2
- LEMD3 | c.1636G>T p.E546* | Nonsense Mutation (SNP) | VAF 48/152 reads (32%) | catalogued as COSV57648165; called by muse, mutect2, varscan2
- LEO1 | c.1867C>A p.L623I | Missense Mutation (SNP) | VAF 26/722 reads (4%) | SIFT tolerated (0.05); PolyPhen benign (0.201); catalogued as COSV100166638; called by muse, mutect2
- LGR6 | c.238G>A p.E80K (on ENST00000367278 / NM_001017403.1; = p.E28K on NM_021636.3) | Missense Mutation (SNP) | VAF 38/156 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.088); catalogued as COSV55151096; called by muse, mutect2, varscan2
- LHFPL3 | c.345C>A p.F115L | Missense Mutation (SNP) | VAF 31/104 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.044); catalogued as COSV67804849, COSV67809572; called by muse, mutect2, varscan2
- LHX4 | c.482G>A p.R161Q | Missense Mutation (SNP) | VAF 31/115 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1558224110, COSV55372640; called by muse, mutect2, varscan2
1,358 further variants in this file (946 protein-altering or splice-affecting, 375 silent, 37 other) are not listed here.
